Somatic mutation profile of tumor specimen HCM-BROD-0719-C43-06B (aliquot HCM-BROD-0719-C43-06B-11D-A85K-36) from HCMI case HCM-BROD-0719-C43, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 66.3 years (24,230 days).
Specimen HCM-BROD-0719-C43-06B: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d255f4f8-b86a-46ce-a4b7-a22ee87d256d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0719-C43-10A (Blood Derived Normal), aliquot HCM-BROD-0719-C43-10A-01D-A85K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5070a7b7-5e4e-41ff-8dee-8694a7699332

The open-access MAF lists 1,515 somatic variants for this specimen: 934 protein-altering or splice-affecting, 520 silent, 61 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 853, Silent 520, Nonsense Mutation 54, Intron 34, Splice Region 10, 3'UTR 9, 5'Flank 9, Frame Shift Del 8, 5'UTR 5, Splice Site 4, RNA 4, In Frame Del 2.

Variants (750 of 1,515; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASXL3 | c.4330C>T p.R1444* | Nonsense Mutation (SNP) | VAF 171/820 reads (21%) | catalogued as rs1555744282, CM1514543, COSV52473481; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 461/870 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- PCED1B | c.1028C>T p.S343F | Missense Mutation (SNP) | VAF 255/1043 reads (24%) | hotspot (GDC flag); SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as rs757280610, COSV71394886, COSV71395186; called by muse, mutect2, varscan2
- RAC1 | c.86C>T p.P29L | Missense Mutation (SNP) | VAF 139/609 reads (23%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.99); catalogued as rs1057519948, COSV61821585, COSV61824963; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.535C>T p.H179Y | Missense Mutation (SNP) | VAF 222/688 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs587780070, CM067054, COSV52662617, COSV52668276, COSV52699993; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- A1CF | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 42/329 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); catalogued as COSV51022223, COSV99257209; called by muse, mutect2, varscan2
- A1CF | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 74/519 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.218); catalogued as COSV50957343, COSV51028098; called by muse, mutect2, varscan2
- ABCA13 | c.644C>T p.S215F | Missense Mutation (SNP) | VAF 159/592 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV70050030; called by muse, mutect2, varscan2
- ABCA9 | c.4835C>T p.P1612L | Missense Mutation (SNP) | VAF 119/594 reads (20%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as rs1460547740, COSV60623259; called by muse, mutect2, varscan2
- ABCC10 | c.1327C>T p.R443C (on ENST00000372530 / NM_001198934.2; = p.R400C on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 76/738 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.958); catalogued as rs866831212, COSV55093460; called by muse, mutect2
- ACSM2B | c.1679G>A p.R560Q | Missense Mutation (SNP) | VAF 94/823 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369392849; called by muse, mutect2, varscan2
- ACSM4 | c.656G>A p.G219E | Missense Mutation (SNP) | VAF 138/628 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.823); catalogued as rs752573137, COSV68066628; called by muse, mutect2, varscan2
- ACTL9 | c.1051G>A p.E351K | Missense Mutation (SNP) | VAF 139/1038 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.049); catalogued as rs868935067, COSV61005285; called by muse, mutect2, varscan2
- ADAMTS8 | c.2545G>A p.G849R | Missense Mutation (SNP) | VAF 114/758 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); catalogued as rs768909867, COSV57294116; called by muse, mutect2, varscan2
- ADAMTSL3 | c.2780A>G p.N927S | Missense Mutation (SNP) | VAF 165/846 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.192); catalogued as rs1382962550; called by muse, mutect2
- ADGRB1 | c.98G>A p.G33E | Missense Mutation (SNP) | VAF 140/1147 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.039); catalogued as rs553052333; called by muse, mutect2, varscan2
- ADGRB2 | c.3683C>T p.S1228F | Missense Mutation (SNP) | VAF 107/803 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV57079105; called by muse, mutect2, varscan2
- ADGRG4 | c.8192C>T p.S2731F | Missense Mutation (SNP) | VAF 60/250 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV54950730; called by muse, mutect2, varscan2
- ADGRL4 | c.1643C>T p.S548L | Missense Mutation (SNP) | VAF 93/670 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs191635062; called by muse, mutect2, varscan2
- AGAP2 | c.2437C>T p.P813S (on ENST00000547588 / NM_001122772.2; = p.P477S on NM_014770.4) | Missense Mutation (SNP) | VAF 131/498 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0.01); catalogued as rs776359629; called by muse, mutect2, varscan2
- AHNAK | c.6353C>T p.S2118F | Missense Mutation (SNP) | VAF 109/1025 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1281811777, COSV57236253; called by muse, mutect2, varscan2
- AIFM3 | c.1093G>A p.E365K | Missense Mutation (SNP) | VAF 78/772 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.026); catalogued as rs868239600, COSV58999252; called by muse, mutect2
- AKAP6 | c.389C>T p.S130F | Missense Mutation (SNP) | VAF 97/643 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55215991; called by muse, mutect2, varscan2
- ALOX12B | c.315G>A p.M105I | Missense Mutation (SNP) | VAF 60/757 reads (8%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as COSV59872335; called by muse, mutect2
- AMBRA1 | c.2746C>T p.P916S (on ENST00000458649 / NM_001367468.1; = p.P826S on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 90/814 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.3); catalogued as rs1482583665, COSV54053338; called by muse, mutect2, varscan2
- AMER3 | c.55G>A p.E19K | Missense Mutation (SNP) | VAF 111/872 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs757285578, COSV58470556; called by muse, mutect2, varscan2
- AMER3 | c.481C>T p.R161W | Missense Mutation (SNP) | VAF 80/914 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.071); catalogued as rs949105785, COSV58465006; called by muse, mutect2
- AMER3 | c.1169C>T p.S390F | Missense Mutation (SNP) | VAF 185/950 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.427); catalogued as COSV58465537; called by muse, mutect2, varscan2
- AMPH | c.1498C>T p.P500S | Missense Mutation (SNP) | VAF 247/917 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV57745942; called by muse, mutect2, varscan2
- ANK3 | c.10102G>A p.D3368N | Missense Mutation (SNP) | VAF 61/764 reads (8%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as rs1391701739; called by muse, mutect2
- ANK3 | c.1423C>T p.R475C | Missense Mutation (SNP) | VAF 127/595 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55065523; called by muse, mutect2, varscan2
- ANKRD44 | c.196C>T p.R66C | Missense Mutation (SNP) | VAF 50/848 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs925366258, COSV56567963; called by muse, mutect2
- ANKRD62 | c.1339C>T p.Q447* | Nonsense Mutation (SNP) | VAF 48/464 reads (10%) | catalogued as COSV100019304; called by muse, mutect2, varscan2
- AOAH | c.1305C>T p.L435= | Splice Region (SNP) | VAF 15/445 reads (3%) | catalogued as rs1029681942, COSV51737002; called by muse, mutect2
- ARHGAP23 | c.1894C>T p.R632C | Missense Mutation (SNP) | VAF 198/866 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1478689591; called by muse, mutect2, varscan2
- ARHGAP30 | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 35/524 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV63515710; called by muse, mutect2
- ARID1B | c.6517C>T p.P2173S | Missense Mutation (SNP) | VAF 184/802 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); catalogued as rs1355205710; called by muse, mutect2, varscan2
- ARSI | c.1622G>A p.R541Q | Missense Mutation (SNP) | VAF 51/912 reads (6%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.007); catalogued as rs753698136; called by muse, mutect2
- ATAD2 | c.227C>T p.S76F | Missense Mutation (SNP) | VAF 100/711 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.259); catalogued as rs1449789129, COSV54884110; called by muse, mutect2, varscan2
- ATP13A5 | c.1276C>T p.P426S | Missense Mutation (SNP) | VAF 71/432 reads (16%) | SIFT tolerated (0.48); PolyPhen benign (0.01); catalogued as COSV100665450; called by muse, mutect2, varscan2
- ATP1A1 | c.2203G>A p.G735R | Missense Mutation (SNP) | VAF 93/749 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55190478; called by muse, mutect2, varscan2
- B3GALT1 | c.596G>A p.R199Q | Missense Mutation (SNP) | VAF 216/819 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.301); catalogued as rs755628484, COSV59908038; called by muse, mutect2, varscan2
- B3GALT2 | c.512G>A p.R171Q | Missense Mutation (SNP) | VAF 34/744 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1253584043; called by muse, mutect2
- BCL2 | c.232C>T p.P78S | Missense Mutation (SNP) | VAF 267/1370 reads (19%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs753603356; called by muse, mutect2, varscan2
- BCL2L14 | c.535G>A p.E179K | Missense Mutation (SNP) | VAF 40/863 reads (5%) | SIFT tolerated (0.75); PolyPhen benign (0.059); catalogued as rs759558587, COSV53786071; called by muse, mutect2
- BICC1 | c.53C>T p.S18F | Missense Mutation (SNP) | VAF 68/984 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.962); catalogued as rs762678309; called by muse, mutect2
- BMP2 | c.1075G>A p.A359T | Missense Mutation (SNP) | VAF 124/772 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66577217; called by muse, mutect2, varscan2
- BPIFC | c.1225C>T p.L409F | Missense Mutation (SNP) | VAF 207/751 reads (28%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.911); catalogued as COSV100301318; called by muse, mutect2, varscan2
- BRDT | c.979G>A p.D327N | Missense Mutation (SNP) | VAF 38/359 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.418); catalogued as COSV62864459; called by muse, mutect2, varscan2
- BRINP1 | c.2138G>A p.G713E | Missense Mutation (SNP) | VAF 96/945 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.711); catalogued as rs867228633; called by muse, mutect2
- BRINP1 | c.410G>C p.G137A | Missense Mutation (SNP) | VAF 61/624 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56310071; called by muse, mutect2, varscan2
- BRMS1L | c.346C>T p.R116C | Missense Mutation (SNP) | VAF 53/340 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1333187829, COSV53762160; called by muse, mutect2, varscan2
- BSN | c.10714G>A p.E3572K | Missense Mutation (SNP) | VAF 32/498 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56525267; called by muse, mutect2
- C12orf50 | c.1172G>A p.R391Q | Missense Mutation (SNP) | VAF 94/434 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as rs776851924, COSV53893621; called by muse, mutect2, varscan2
- C19orf38 | c.19C>T p.L7F | Missense Mutation (SNP) | VAF 99/810 reads (12%) | SIFT tolerated (0.41); PolyPhen benign (0.027); catalogued as COSV67318744; called by muse, mutect2, varscan2
- C3orf56 | c.442G>A p.A148T | Missense Mutation (SNP) | VAF 123/589 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.263); catalogued as rs772457088; called by muse, mutect2, varscan2
- C6 | c.1333C>T p.R445* | Nonsense Mutation (SNP) | VAF 38/569 reads (7%) | catalogued as rs778044260, COSV54706799; called by muse, mutect2
- C6orf132 | c.272G>A p.G91E | Missense Mutation (SNP) | VAF 76/577 reads (13%) | SIFT deleterious (0); catalogued as rs1477496917; called by muse, mutect2, varscan2
- C6orf136 | c.634C>T p.R212C (on ENST00000376473 / NM_001109938.3; = p.R78C on NM_145029.4) | Missense Mutation (SNP) | VAF 159/1255 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs1359767593, COSV53315954; called by muse, mutect2, varscan2
- C9 | c.187C>T p.R63C | Missense Mutation (SNP) | VAF 65/403 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs749534250, COSV54674594; called by muse, mutect2, varscan2
- CAMK2B | c.1538C>T p.S513L | Missense Mutation (SNP) | VAF 206/758 reads (27%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as rs771401633; called by muse, varscan2
- CAPN6 | c.109G>A p.D37N | Missense Mutation (SNP) | VAF 117/476 reads (25%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.698); catalogued as COSV60694985; called by muse, mutect2, varscan2
- CAPZA3 | c.775G>A p.D259N | Missense Mutation (SNP) | VAF 60/772 reads (8%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.562); catalogued as COSV56851099, COSV99856026; called by muse, mutect2
- CBX4 | c.535G>A p.E179K | Missense Mutation (SNP) | VAF 314/1307 reads (24%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.991); catalogued as COSV99490321; called by muse, mutect2, varscan2
- CCDC62 | c.391C>T p.L131F | Missense Mutation (SNP) | VAF 71/415 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV99457143, COSV99457740; called by muse, mutect2, varscan2
- CD86 | c.269C>T p.S90L (on ENST00000330540 / NM_175862.5; = p.S84L on NM_006889.4) | Missense Mutation (SNP) | VAF 57/1128 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.037); catalogued as rs761419249, COSV52609967; called by muse, mutect2
- CDH9 | c.1849G>A p.V617I | Missense Mutation (SNP) | VAF 47/622 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs564401936, COSV50282071, COSV50318030; called by muse, mutect2
- CDK7 | c.482C>T p.S161F | Missense Mutation (SNP) | VAF 88/852 reads (10%) | SIFT tolerated (0.76); PolyPhen benign (0.015); catalogued as COSV56514406, COSV99841689; called by muse, mutect2, varscan2
- CFHR4 | c.1682C>T p.S561L (on ENST00000367416 / NM_001201551.2; = p.S315L on NM_006684.5) | Missense Mutation (SNP) | VAF 18/426 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.379); catalogued as COSV52233675; called by muse, mutect2
- CHL1 | c.3613C>T p.P1205S (on ENST00000397491 / NM_001253387.1; = p.P1221S on NM_006614.4) | Missense Mutation (SNP) | VAF 47/410 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.349); catalogued as COSV56606118; called by muse, mutect2, varscan2
- CHTF18 | c.514C>T p.P172S | Missense Mutation (SNP) | VAF 282/1230 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs764039390; called by muse, mutect2, varscan2
- CHTF18 | c.515C>T p.P172L | Missense Mutation (SNP) | VAF 282/1231 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as rs377536379; called by muse, mutect2, varscan2
- CLMN | c.1087C>T p.R363C | Missense Mutation (SNP) | VAF 102/713 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs774934404, COSV54184777; called by muse, mutect2, varscan2
- CLSTN2 | c.2371C>T p.H791Y | Missense Mutation (SNP) | VAF 39/578 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.7); catalogued as COSV71723680; called by muse, mutect2
- CLVS2 | c.565G>A p.D189N | Missense Mutation (SNP) | VAF 58/556 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.654); catalogued as COSV51559200; called by muse, mutect2
- CNGA4 | c.1601G>A p.W534* | Nonsense Mutation (SNP) | VAF 41/867 reads (5%) | catalogued as rs1349875575; called by muse, mutect2
- CNTNAP5 | c.889G>A p.E297K | Missense Mutation (SNP) | VAF 141/626 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.317); catalogued as rs760964233, COSV70473108; called by muse, mutect2, varscan2
- COL16A1 | c.3725C>T p.P1242L | Missense Mutation (SNP) | VAF 67/609 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs764024407; called by muse, mutect2, varscan2
- COL21A1 | c.1169G>A p.G390E | Missense Mutation (SNP) | VAF 126/538 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.532); catalogued as rs867965409, COSV55169986; called by muse, mutect2, varscan2
- COL26A1 | c.263C>T p.P88L | Missense Mutation (SNP) | VAF 114/682 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); catalogued as COSV100561658, COSV100561961; called by muse, mutect2, varscan2
- COL3A1 | c.4211G>A p.G1404E | Missense Mutation (SNP) | VAF 52/714 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV58590417; called by muse, mutect2
- COL5A1 | c.433G>A p.G145R | Missense Mutation (SNP) | VAF 104/1047 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.416); catalogued as COSV100880603, COSV65668041; called by muse, mutect2
- COL6A3 | c.4598G>A p.G1533E | Missense Mutation (SNP) | VAF 156/874 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs994572495; called by muse, mutect2, varscan2
- COL6A3 | c.361G>A p.G121R | Missense Mutation (SNP) | VAF 35/678 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55110905; called by muse, mutect2
- COL6A5 | c.895C>T p.Q299* | Nonsense Mutation (SNP) | VAF 126/627 reads (20%) | catalogued as COSV55215142; called by muse, mutect2, varscan2
- COL6A5 | c.4534G>A p.G1512R | Missense Mutation (SNP) | VAF 46/776 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55218236; called by muse, mutect2
- CTNNBL1 | c.761C>T p.P254L | Missense Mutation (SNP) | VAF 63/726 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.076); catalogued as rs1239080765, COSV63745065; called by muse, mutect2
- CUL1 | c.2233C>T p.R745* | Nonsense Mutation (SNP) | VAF 526/1081 reads (49%) | catalogued as COSV57387452; called by muse, mutect2, varscan2
- CYP11B1 | c.367C>T p.R123C | Missense Mutation (SNP) | VAF 88/768 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.284); catalogued as rs145050906; called by muse, mutect2, varscan2
- CYP4A22 | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 85/627 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs568254542; called by muse, mutect2, varscan2
- DDAH1 | c.478G>A p.D160N | Missense Mutation (SNP) | VAF 59/434 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.177); catalogued as rs368917983; called by muse, mutect2, varscan2
- DDX31 | c.215G>A p.R72K | Missense Mutation (SNP) | VAF 252/1239 reads (20%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.364); catalogued as rs866139523, COSV60135982; called by muse, mutect2, varscan2
- DEFB113 | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 186/895 reads (21%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.012); catalogued as COSV59038722; called by muse, mutect2, varscan2
- DGAT2L6 | c.710C>T p.P237L | Missense Mutation (SNP) | VAF 103/471 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.438); catalogued as COSV100283926; called by muse, mutect2, varscan2
- DGCR8 | c.820C>T p.P274S | Missense Mutation (SNP) | VAF 348/1112 reads (31%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV100708007; called by muse, mutect2, varscan2
- DLGAP2 | c.1001C>T p.P334L | Missense Mutation (SNP) | VAF 418/1501 reads (28%) | SIFT tolerated (0.66); PolyPhen probably damaging (0.998); catalogued as rs1404079466, COSV70098229; called by muse, mutect2, varscan2
- DMRT3 | c.205G>A p.A69T | Missense Mutation (SNP) | VAF 156/1051 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51904788; called by muse, mutect2, varscan2
- DNAH17 | c.8758A>G p.K2920E | Missense Mutation (SNP) | VAF 96/548 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); catalogued as rs1411496053; called by muse, mutect2, varscan2
- DNAH5 | c.8836C>T p.R2946C | Missense Mutation (SNP) | VAF 56/416 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.168); catalogued as rs150899380; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH5 | c.6283G>A p.E2095K | Missense Mutation (SNP) | VAF 71/575 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54210405; called by muse, mutect2, varscan2
- DNAH6 | c.4582C>T p.R1528* | Nonsense Mutation (SNP) | VAF 146/687 reads (21%) | catalogued as rs1419215092; called by muse, mutect2, varscan2
- DNAH7 | c.12025G>A p.E4009K | Missense Mutation (SNP) | VAF 138/616 reads (22%) | SIFT tolerated (0.83); PolyPhen benign (0.271); catalogued as COSV56789359; called by muse, mutect2, varscan2
- DNAH7 | c.11012C>T p.S3671L | Missense Mutation (SNP) | VAF 199/902 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs868695698, COSV56755601; called by muse, mutect2, varscan2
- DNAH7 | c.175C>T p.P59S | Missense Mutation (SNP) | VAF 56/904 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as rs1476375494; called by muse, mutect2
- DNAI2 | c.37G>A p.E13K | Missense Mutation (SNP) | VAF 75/1031 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV104408150; called by muse, mutect2
- DNAJC18 | c.553C>T p.P185S | Missense Mutation (SNP) | VAF 45/378 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs1047004381, COSV57415915; called by muse, mutect2, varscan2
- DOC2A | c.358G>A p.D120N | Missense Mutation (SNP) | VAF 72/603 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV58750920; called by muse, mutect2, varscan2
- DOCK8 | c.4159G>A p.D1387N | Missense Mutation (SNP) | VAF 159/682 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.025); catalogued as rs182516558, COSV66619160; called by muse, mutect2, varscan2
- DPPA4 | c.830C>T p.P277L | Missense Mutation (SNP) | VAF 111/742 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59509498, COSV59511688; called by muse, mutect2, varscan2
- DSCAM | c.1787C>T p.P596L | Missense Mutation (SNP) | VAF 145/568 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1182107464, COSV68023174, COSV68028509; called by muse, mutect2, varscan2
- DTX2 | c.256C>T p.R86C | Missense Mutation (SNP) | VAF 129/612 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370872905; called by muse, mutect2, varscan2
- EIF5A2 | c.325C>T p.R109C | Missense Mutation (SNP) | VAF 46/648 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.222); catalogued as rs761918940, COSV55543526; called by muse, mutect2
- ELAPOR2 | c.2729G>A p.G910E (on ENST00000450689 / NM_001142749.3; = p.G743E on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 117/720 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV51890997; called by muse, mutect2, varscan2
- ELN | c.1747G>A p.G583S (on ENST00000320399 / NM_001278939.1; = p.V583I on NM_000501.4) | Missense Mutation (SNP) | VAF 208/1317 reads (16%) | catalogued as rs1563857335; called by muse, mutect2, varscan2
- EMILIN2 | c.346G>A p.G116R | Missense Mutation (SNP) | VAF 124/780 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0.356); catalogued as COSV54423432; called by muse, mutect2, varscan2
- EP300 | c.2170C>T p.P724S | Missense Mutation (SNP) | VAF 155/1087 reads (14%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.298); catalogued as COSV54328039; called by muse, mutect2, varscan2
- EPHA7 | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 48/471 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs867992353, COSV65169827; called by muse, mutect2, varscan2
- EPPK1 | c.6250C>T p.P2084S | Missense Mutation (SNP) | VAF 276/1128 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.225); catalogued as rs781812162; called by muse, mutect2, varscan2
- ERAP1 | c.347C>T p.S116L | Missense Mutation (SNP) | VAF 130/965 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as rs748728833, COSV57091417; called by muse, mutect2, varscan2
- ERC2 | c.1590G>A p.M530I | Missense Mutation (SNP) | VAF 58/866 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as rs746216863, COSV55646106; called by muse, mutect2
- ERC2 | c.641C>T p.S214F | Missense Mutation (SNP) | VAF 120/534 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.125); catalogued as COSV99881829; called by muse, mutect2, varscan2
- ERGIC1 | c.523G>A p.D175N | Missense Mutation (SNP) | VAF 95/659 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.111); catalogued as rs1380560769; called by muse, mutect2, varscan2
- ESPN | c.2857C>T p.R953C | Missense Mutation (SNP) | VAF 300/1069 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as rs918162945; called by muse, mutect2, varscan2
- ESPN | c.3938C>T p.T1313I | Missense Mutation (SNP) | VAF 103/947 reads (11%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.711); catalogued as rs377237348; called by muse, mutect2, varscan2
- EXD3 | c.1918G>A p.G640R | Missense Mutation (SNP) | VAF 111/1018 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs767343485; called by muse, mutect2, varscan2
- EYA2 | c.1436G>A p.G479E | Missense Mutation (SNP) | VAF 124/597 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57938790; called by muse, mutect2, varscan2
- FAM186B | c.2287G>A p.A763T | Missense Mutation (SNP) | VAF 60/800 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0.028); catalogued as rs745528985; called by muse, mutect2
- FAM20C | c.764C>T p.S255F | Missense Mutation (SNP) | VAF 249/960 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.347); catalogued as rs1185184378, COSV58237723; called by muse, mutect2, varscan2
- FAM234B | c.1637C>T p.S546L | Missense Mutation (SNP) | VAF 47/752 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.659); catalogued as COSV99545256; called by muse, mutect2
- FAM83B | c.1718G>A p.G573E | Missense Mutation (SNP) | VAF 108/925 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV60921012; called by muse, mutect2, varscan2
- FAM83B | c.2501C>T p.S834F | Missense Mutation (SNP) | VAF 75/705 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.401); catalogued as rs868381299, COSV60922538; called by muse, mutect2, varscan2
- FANCA | c.2395C>T p.P799S | Missense Mutation (SNP) | VAF 213/948 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as rs762439008, COSV59796894; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FAT4 | c.6541G>A p.G2181R | Missense Mutation (SNP) | VAF 77/578 reads (13%) | SIFT tolerated (0.64); PolyPhen benign (0.012); catalogued as COSV58704201; called by muse, mutect2, varscan2
- FAT4 | c.13124G>A p.G4375E | Missense Mutation (SNP) | VAF 98/488 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.049); catalogued as rs767377691; called by muse, varscan2
- FBH1 | c.2143A>G p.I715V (on ENST00000362091 / NM_178150.3; = p.I766V on NM_032807.4) | Missense Mutation (SNP) | VAF 92/498 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.068); catalogued as rs755158548; called by muse, mutect2, varscan2
- FBN3 | c.1127G>A p.G376E | Missense Mutation (SNP) | VAF 158/933 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as rs772381752; called by muse, mutect2, varscan2
- FBXO40 | c.2062C>T p.R688C | Missense Mutation (SNP) | VAF 317/956 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.409); catalogued as rs755825702, COSV57523498; called by muse, mutect2, varscan2
- FER1L6 | c.4135C>T p.P1379S | Missense Mutation (SNP) | VAF 61/618 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67548786; called by muse, mutect2, varscan2
- FHL5 | c.160G>A p.D54N | Missense Mutation (SNP) | VAF 70/449 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs746596116, COSV100459801; called by muse, mutect2, varscan2
- FHOD3 | c.2704C>T p.R902W (on ENST00000359247 / NM_001281739.3; = p.R919W on NM_025135.5) | Missense Mutation (SNP) | VAF 226/908 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs369206677; called by muse, mutect2, varscan2
- FLT4 | c.96G>T p.L32F | Missense Mutation (SNP) | VAF 92/733 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56104022, COSV56105611; called by muse, mutect2, varscan2
- FREM1 | c.3592G>A p.D1198N | Missense Mutation (SNP) | VAF 245/722 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs772523599, COSV66528833; called by muse, mutect2, varscan2
- FSCB | c.1678C>T p.Q560* | Nonsense Mutation (SNP) | VAF 97/672 reads (14%) | catalogued as rs768925200; called by muse, mutect2, varscan2
- FSIP2 | c.10441G>A p.E3481K | Missense Mutation (SNP) | VAF 20/450 reads (4%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.497); catalogued as rs958959777; called by muse, mutect2
- FSIP2 | c.11635G>A p.E3879K | Missense Mutation (SNP) | VAF 114/524 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as COSV58080369; called by muse, mutect2, varscan2
- GABRA3 | c.818G>A p.R273Q | Missense Mutation (SNP) | VAF 83/344 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs772835335, COSV64803103; called by muse, varscan2
- GABRA3 | c.595C>T p.P199S | Missense Mutation (SNP) | VAF 159/426 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64802699; called by muse, varscan2
- GABRB3 | c.1241G>A p.R414Q | Missense Mutation (SNP) | VAF 152/972 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.022); catalogued as rs373229638; called by muse, mutect2, varscan2
- GFRA3 | c.772G>A p.D258N | Missense Mutation (SNP) | VAF 44/676 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.749); catalogued as COSV51228277; called by muse, mutect2
- GIMAP4 | c.125G>A p.G42E | Missense Mutation (SNP) | VAF 155/1422 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55431717; called by muse, mutect2, varscan2
- GIMAP6 | c.28C>T p.P10S | Missense Mutation (SNP) | VAF 409/859 reads (48%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as rs774846551, COSV61033479; called by muse, varscan2
- GJD2 | c.617G>A p.R206Q | Missense Mutation (SNP) | VAF 183/1020 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs995766804, COSV51747367; called by muse, mutect2, varscan2
- GNA11 | c.1057C>A p.L353I | Missense Mutation (SNP) | VAF 38/808 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV50018555, COSV50019645; called by muse, mutect2
- GNGT1 | c.69G>C p.K23N | Missense Mutation (SNP) | VAF 65/784 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.44); catalogued as rs1187165979; called by muse, mutect2
- GPATCH8 | c.3619C>T p.P1207S | Missense Mutation (SNP) | VAF 185/926 reads (20%) | SIFT tolerated (0.75); PolyPhen benign (0.053); catalogued as rs780037640; called by muse, mutect2, varscan2
- GPBP1 | c.256C>T p.H86Y | Missense Mutation (SNP) | VAF 101/836 reads (12%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.558); catalogued as COSV99303058; called by muse, mutect2, varscan2
- GPLD1 | c.2200G>A p.E734K | Missense Mutation (SNP) | VAF 91/396 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV57762126; called by muse, mutect2, varscan2
- GPX5 | c.476C>T p.P159L | Missense Mutation (SNP) | VAF 88/696 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.147); catalogued as rs1490116681, COSV101297272; called by muse, mutect2, varscan2
- GRIA2 | c.245C>T p.S82L | Missense Mutation (SNP) | VAF 74/436 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52385092; called by muse, mutect2, varscan2
- GRID2 | c.706C>T p.P236S | Missense Mutation (SNP) | VAF 105/538 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs367770083, COSV99940437; called by muse, mutect2, varscan2
- GRIK5 | c.181G>A p.A61T | Missense Mutation (SNP) | VAF 106/886 reads (12%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.563); catalogued as COSV99490411; called by muse, mutect2, varscan2
- GRIN2A | c.3199C>T p.R1067W | Missense Mutation (SNP) | VAF 116/1011 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58021247; called by muse, mutect2, varscan2
- GRM7 | c.1108G>A p.E370K | Missense Mutation (SNP) | VAF 58/824 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV63158538; called by muse, mutect2
- GRM8 | c.2618G>A p.G873E | Missense Mutation (SNP) | VAF 93/1132 reads (8%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.461); catalogued as COSV58807935; called by muse, mutect2
- GRN | c.194C>G p.A65G | Missense Mutation (SNP) | VAF 185/957 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.009); catalogued as COSV99275119; called by muse, mutect2, varscan2
- HECW2 | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 45/399 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99647449; called by muse, mutect2, varscan2
- HERC2 | c.4282C>T p.P1428S | Missense Mutation (SNP) | VAF 148/885 reads (17%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.979); catalogued as COSV55324530; called by muse, mutect2, varscan2
- HFM1 | c.1255G>A p.E419K | Missense Mutation (SNP) | VAF 52/504 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.479); catalogued as COSV54020696; called by muse, mutect2, varscan2
- HHLA1 | c.989C>T p.S330L | Missense Mutation (SNP) | VAF 64/592 reads (11%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs369879360, COSV51841488; called by muse, mutect2, varscan2
- HIPK2 | c.3221C>T p.P1074L | Missense Mutation (SNP) | VAF 156/1485 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.258); catalogued as rs775752128; called by muse, mutect2, varscan2
- HIVEP1 | c.3419A>G p.N1140S | Missense Mutation (SNP) | VAF 81/806 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs376351349; called by muse, mutect2, varscan2
- HNRNPCL1 | c.296G>A p.R99Q | Missense Mutation (SNP) | VAF 149/1190 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.63); catalogued as rs150230498; called by muse, mutect2, varscan2
- HNRNPM | c.1195C>T p.P399S | Missense Mutation (SNP) | VAF 45/1029 reads (4%) | SIFT tolerated (0.51); PolyPhen benign (0.166); catalogued as COSV99725623; called by muse, mutect2
- HROB | c.209A>G p.E70G | Missense Mutation (SNP) | VAF 72/1130 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.234); catalogued as rs1385057688; called by muse, mutect2
- HS3ST4 | c.1184C>T p.P395L | Missense Mutation (SNP) | VAF 196/821 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV58807895; called by muse, mutect2, varscan2
- HSD17B3 | c.266C>T p.A89V | Missense Mutation (SNP) | VAF 98/835 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as COSV64557884; called by muse, mutect2, varscan2
- HSPB2 | c.397C>T p.R133* | Nonsense Mutation (SNP) | VAF 58/804 reads (7%) | catalogued as COSV57052937; called by muse, mutect2
- HUNK | c.1477C>T p.P493S | Missense Mutation (SNP) | VAF 68/517 reads (13%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.003); catalogued as COSV54227789; called by muse, mutect2, varscan2
- IGFN1 | c.3299C>T p.T1100I (on ENST00000295591 / NM_001367841.1; = p.T3557I on NM_001164586.2) | Missense Mutation (SNP) | VAF 133/873 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs151328965; called by muse, mutect2, varscan2
- IGLL1 | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 89/865 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.302); catalogued as rs1487300715, COSV50770149; called by muse, mutect2, varscan2
- IL1R1 | c.128C>T p.P43L | Missense Mutation (SNP) | VAF 66/716 reads (9%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs188550005, COSV52108737; called by muse, mutect2
- IL21R | c.1058C>T p.P353L | Missense Mutation (SNP) | VAF 128/1102 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs550842554, COSV100559944; called by muse, mutect2, varscan2
- INAVA | c.1709C>T p.S570F | Missense Mutation (SNP) | VAF 145/887 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.768); catalogued as rs1445660039; called by muse, mutect2, varscan2
- INO80C | c.503C>T p.S168F | Missense Mutation (SNP) | VAF 87/784 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as rs749802095, COSV58047420; called by muse, mutect2, varscan2
- IQSEC1 | c.2089C>T p.R697C | Missense Mutation (SNP) | VAF 165/694 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs200895339; called by muse, mutect2, varscan2
- ISLR2 | c.52G>A p.G18R | Missense Mutation (SNP) | VAF 50/983 reads (5%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV62303604; called by muse, mutect2
- JPH4 | c.638C>T p.P213L | Missense Mutation (SNP) | VAF 147/981 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.086); catalogued as rs1226755149; called by muse, mutect2, varscan2
- KBTBD7 | c.1984T>A p.F662I | Missense Mutation (SNP) | VAF 52/717 reads (7%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as rs774208807; called by muse, mutect2
- KCNJ11 | c.908C>T p.S303F | Missense Mutation (SNP) | VAF 180/961 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60594814; called by muse, mutect2, varscan2
- KCNJ12 | c.278C>T p.A93V | Missense Mutation (SNP) | VAF 177/1697 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs1555562489; called by muse, mutect2, varscan2
- KCTD13 | c.620A>T p.H207L | Missense Mutation (SNP) | VAF 129/863 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as rs748489378; called by muse, mutect2, varscan2
- KDM4E | c.464G>A p.G155E | Missense Mutation (SNP) | VAF 85/629 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs1555102708; called by muse, mutect2, varscan2
- KDR | c.3928C>T p.H1310Y | Missense Mutation (SNP) | VAF 153/689 reads (22%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as COSV55770242; called by muse, mutect2, varscan2
- KIAA0319 | c.973C>T p.P325S | Missense Mutation (SNP) | VAF 69/596 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.073); catalogued as COSV100985819, COSV99068301; called by muse, mutect2, varscan2
- KIF13A | c.1315G>A p.G439S | Missense Mutation (SNP) | VAF 96/816 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52449004, COSV52454731; called by muse, mutect2, varscan2
- KIF1B | c.1931G>T p.R644L (on ENST00000377086 / NM_001365952.1; = p.R598L on NM_015074.3) | Missense Mutation (SNP) | VAF 93/789 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.373); catalogued as COSV99028882; called by muse, mutect2, varscan2
- KIF2A | c.823C>T p.R275C | Missense Mutation (SNP) | VAF 65/461 reads (14%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.999); catalogued as rs1375651707, COSV66945575; called by muse, mutect2, varscan2
- KIF5A | c.430C>T p.R144C | Missense Mutation (SNP) | VAF 25/495 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs978901860, COSV54051656, COSV54056748; called by muse, mutect2
- KIF5A | c.2713C>T p.R905C | Missense Mutation (SNP) | VAF 56/1074 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs758637368; called by muse, mutect2
- KLHDC8A | c.782C>T p.S261L | Missense Mutation (SNP) | VAF 42/626 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.234); catalogued as rs766875332, COSV65679013, COSV65679062; called by muse, mutect2
- KLK13 | c.403C>T p.Q135* | Nonsense Mutation (SNP) | VAF 123/883 reads (14%) | catalogued as rs1234684036; called by mutect2, varscan2
- KRT1 | c.1075G>A p.E359K | Missense Mutation (SNP) | VAF 158/847 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs765763232, COSV52868587; called by muse, mutect2, varscan2
- LAMA3 | c.2285C>T p.A762V | Missense Mutation (SNP) | VAF 185/597 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.017); catalogued as rs773700152; called by muse, mutect2, varscan2
- LAMA5 | c.5540C>T p.P1847L | Missense Mutation (SNP) | VAF 69/619 reads (11%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.973); catalogued as rs1185832797; called by muse, mutect2, varscan2
- LAMA5 | c.4300G>A p.G1434R | Missense Mutation (SNP) | VAF 206/960 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99438212; called by muse, mutect2, varscan2
- LARS1 | c.3385C>T p.P1129S (on ENST00000394434 / NM_020117.11; = p.P1102S on NM_016460.3) | Missense Mutation (SNP) | VAF 74/711 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs765125271, COSV50995456; called by muse, mutect2, varscan2
- LGALS12 | c.400C>T p.H134Y | Missense Mutation (SNP) | VAF 42/607 reads (7%) | SIFT tolerated (1); PolyPhen possibly damaging (0.673); catalogued as rs375808191; called by muse, mutect2
- LGSN | c.1367C>A p.P456H | Missense Mutation (SNP) | VAF 172/705 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101040467, COSV65728436; called by muse, mutect2, varscan2
- LMAN1L | c.37C>T p.L13F | Missense Mutation (SNP) | VAF 156/732 reads (21%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.993); catalogued as rs748029665; called by muse, mutect2, varscan2
- LPA | c.56C>T p.P19L | Missense Mutation (SNP) | VAF 23/358 reads (6%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.284); catalogued as rs1188266967, COSV100307617; called by muse, mutect2
- LPAR4 | c.694C>T p.R232C | Missense Mutation (SNP) | VAF 130/471 reads (28%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.947); catalogued as rs764055600, COSV70912356; called by muse, varscan2
- LRP1B | c.9967C>T p.R3323C | Missense Mutation (SNP) | VAF 55/526 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as rs1328117748, COSV67187455; called by muse, mutect2, varscan2
- LRP5 | c.2123C>T p.S708L | Missense Mutation (SNP) | VAF 79/602 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.037); catalogued as rs532035027; called by muse, mutect2, varscan2
- LRRC15 | c.1097A>G p.N366S | Missense Mutation (SNP) | VAF 109/874 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.46); catalogued as COSV100752868; called by muse, mutect2, varscan2
- LRRC18 | c.256G>A p.D86N | Missense Mutation (SNP) | VAF 177/807 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); catalogued as COSV53282889; called by muse, mutect2, varscan2
- LRRC75B | c.878C>T p.T293I | Missense Mutation (SNP) | VAF 110/1240 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.033); catalogued as rs1424462695; called by muse, mutect2
- MAGI1 | c.2135G>A p.G712E | Missense Mutation (SNP) | VAF 53/758 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58333573, COSV58333615; called by muse, mutect2
- MAGI2 | c.3022C>T p.P1008S | Missense Mutation (SNP) | VAF 92/437 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.16); catalogued as rs764279398; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MALRD1 | c.1318C>T p.P440S | Missense Mutation (SNP) | VAF 65/661 reads (10%) | SIFT tolerated (0.61); PolyPhen benign (0.014); catalogued as rs1303961758; called by muse, mutect2, varscan2
- MAMDC4 | c.605G>A p.R202Q | Missense Mutation (SNP) | VAF 252/806 reads (31%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.58); catalogued as rs371823485; called by muse, mutect2
- MAP1A | c.6338G>A p.G2113E | Missense Mutation (SNP) | VAF 187/858 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1230807332; called by muse, mutect2, varscan2
- MAP3K4 | c.3154C>T p.R1052C | Missense Mutation (SNP) | VAF 30/394 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62338721; called by muse, mutect2
- MBL2 | c.221G>A p.G74E | Missense Mutation (SNP) | VAF 89/799 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64758651; called by muse, mutect2, varscan2
- MBOAT1 | c.1054C>A p.Q352K | Missense Mutation (SNP) | VAF 67/633 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV61123435; called by muse, mutect2, varscan2
- MCF2L2 | c.2884+1G>A p.X962_splice | Splice Site (SNP) | VAF 24/432 reads (6%) | catalogued as COSV100191016; called by muse, mutect2
- MDC1 | c.2005C>G p.P669A | Missense Mutation (SNP) | VAF 270/1195 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.175); catalogued as rs1438462033, COSV64523879; called by muse, mutect2, varscan2
- MEGF10 | c.241C>T p.R81* | Nonsense Mutation (SNP) | VAF 76/491 reads (15%) | catalogued as rs1279221790, COSV57245287; called by muse, mutect2, varscan2
- MFHAS1 | c.1168C>T p.P390S | Missense Mutation (SNP) | VAF 56/926 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.122); catalogued as rs148631416; called by muse, mutect2
- MGAM2 | c.5050C>T p.R1684* | Nonsense Mutation (SNP) | VAF 68/824 reads (8%) | catalogued as rs1271423734; called by muse, mutect2
- MGAT3 | c.83C>T p.T28I | Missense Mutation (SNP) | VAF 323/1256 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.118); catalogued as rs751039442; called by muse, mutect2, varscan2
- MLLT1 | c.613C>T p.P205S | Missense Mutation (SNP) | VAF 157/822 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as rs1351320172; called by muse, mutect2, varscan2
- MON2 | c.2524C>T p.L842F | Missense Mutation (SNP) | VAF 60/513 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99743572; called by muse, mutect2, varscan2
- MROH2B | c.4307C>T p.S1436L | Missense Mutation (SNP) | VAF 68/582 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.183); catalogued as rs867528082, COSV68182690; called by muse, mutect2, varscan2
- MROH5 | c.2567G>A p.R856Q | Missense Mutation (SNP) | VAF 135/991 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.118); catalogued as rs772289155, COSV71302591; called by muse, mutect2, varscan2
- MROH5 | c.41C>T p.P14L | Missense Mutation (SNP) | VAF 186/746 reads (25%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.003); catalogued as rs199532269; called by muse, varscan2
- MSR1 | c.1009G>A p.E337K | Missense Mutation (SNP) | VAF 50/674 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.517); catalogued as COSV50534475; called by muse, mutect2
- MTM1 | c.1490C>T p.S497F | Missense Mutation (SNP) | VAF 30/227 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60333561; called by muse, mutect2, varscan2
- MUC16 | c.24704G>A p.R8235K | Missense Mutation (SNP) | VAF 86/896 reads (10%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0.047); catalogued as COSV101199918; called by muse, mutect2
- MUC16 | c.10142C>T p.S3381L | Missense Mutation (SNP) | VAF 103/834 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.958); catalogued as COSV67457343; called by muse, mutect2, varscan2
- MUC16 | c.6595G>A p.D2199N | Missense Mutation (SNP) | VAF 121/629 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.908); catalogued as rs967202886, COSV67447777; called by muse, mutect2, varscan2
- MUC16 | c.707C>T p.S236F | Missense Mutation (SNP) | VAF 95/845 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.266); catalogued as rs533548881, COSV67444798; called by muse, mutect2, varscan2
- MUC17 | c.11755C>T p.P3919S | Missense Mutation (SNP) | VAF 133/1147 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.103); catalogued as rs865774883, COSV60281359; called by muse, mutect2, varscan2
- MUC4 | c.2009C>T p.S670F | Missense Mutation (SNP) | VAF 185/1305 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.496); catalogued as rs1013696488; called by muse, mutect2, varscan2
- MYD88 | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 190/787 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.699); catalogued as rs780309112; called by muse, mutect2, varscan2
- MYLK2 | c.364G>A p.D122N | Missense Mutation (SNP) | VAF 296/1261 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV65659995; called by muse, mutect2, varscan2
- MYO15A | c.3088C>T p.P1030S | Missense Mutation (SNP) | VAF 297/1169 reads (25%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); catalogued as rs901580087; called by muse, mutect2, varscan2
- MYO5B | c.1312G>A p.D438N | Missense Mutation (SNP) | VAF 84/527 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs758462557; called by muse, mutect2, varscan2
- MYOM3 | c.3653G>A p.R1218K | Missense Mutation (SNP) | VAF 90/776 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as rs1365027118; called by muse, mutect2, varscan2
- NACA2 | c.431G>A p.R144K | Missense Mutation (SNP) | VAF 75/1125 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs879177143; called by muse, mutect2
- NEBL | c.2033G>A p.R678Q | Missense Mutation (SNP) | VAF 102/660 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.151); catalogued as rs774294999, COSV65802298; ClinVar: uncertain significance; called by muse, mutect2
- NEBL | c.1216C>T p.L406F | Missense Mutation (SNP) | VAF 58/527 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV65805270; called by muse, mutect2, varscan2
- NFKBIE | c.1447C>T p.L483F (on ENST00000275015; = p.L344F on NM_004556.3) | Missense Mutation (SNP) | VAF 61/468 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.593); catalogued as rs1561912982; called by muse, mutect2, varscan2
- NLRP5 | c.1672G>A p.E558K | Missense Mutation (SNP) | VAF 93/597 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as rs1171933575, COSV66763843; called by muse, mutect2, varscan2
- NOD2 | c.1960G>A p.G654R | Missense Mutation (SNP) | VAF 153/783 reads (20%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs777290315; called by muse, mutect2, varscan2
- NPAP1 | c.1985C>T p.P662L | Missense Mutation (SNP) | VAF 166/1060 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as COSV61507773; called by muse, mutect2, varscan2
- NTN4 | c.116G>A p.G39E | Missense Mutation (SNP) | VAF 72/1028 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs377066696; called by muse, mutect2
- NUMBL | c.338C>T p.S113F | Missense Mutation (SNP) | VAF 89/644 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.906); catalogued as COSV53284724; called by muse, mutect2, varscan2
- NUP188 | c.1322C>T p.P441L | Missense Mutation (SNP) | VAF 96/758 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1318372362; called by muse, mutect2, varscan2
- NWD1 | c.1252C>T p.H418Y | Missense Mutation (SNP) | VAF 88/648 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.987); catalogued as rs574266944, COSV60338960; called by muse, mutect2, varscan2
- NXF3 | c.1195A>C p.N399H | Missense Mutation (SNP) | VAF 45/303 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67704109; called by muse, mutect2, varscan2
- NYNRIN | c.3098C>T p.S1033F | Missense Mutation (SNP) | VAF 110/956 reads (12%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); catalogued as COSV66841476, COSV66841834; called by muse, mutect2, varscan2
- OOSP4A | c.260G>A p.G87D | Missense Mutation (SNP) | VAF 42/499 reads (8%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.712); catalogued as rs1186247358; called by muse, mutect2
- OR10W1 | c.864G>A p.M288I | Missense Mutation (SNP) | VAF 66/477 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV67720858; called by muse, mutect2, varscan2
- OR13C3 | c.774G>A p.M258I | Missense Mutation (SNP) | VAF 105/954 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV66165629; called by muse, mutect2, varscan2
- OR13C5 | c.166C>T p.H56Y | Missense Mutation (SNP) | VAF 123/824 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV101053037; called by muse, mutect2, varscan2
- OR1D2 | c.471del p.I158Yfs*6 | Frame Shift Del (DEL) | VAF 72/705 reads (10%) | catalogued as COSV58921501; called by mutect2, pindel, varscan2
- OR2J2 | c.470C>T p.S157L | Missense Mutation (SNP) | VAF 279/1203 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1281116046; called by muse, mutect2, varscan2
- OR2M2 | c.917G>A p.G306E | Missense Mutation (SNP) | VAF 44/834 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV62898059, COSV62899018; called by muse, mutect2
- OR2M5 | c.700C>T p.R234C | Missense Mutation (SNP) | VAF 74/978 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs139017053; called by muse, mutect2
- OR2T27 | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1475990469, COSV100788381; called by mutect2, varscan2
- OR2W3 | c.301C>T p.L101F | Missense Mutation (SNP) | VAF 183/907 reads (20%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV64457589; called by muse, mutect2, varscan2
- OR4A47 | c.689G>A p.G230E | Missense Mutation (SNP) | VAF 91/849 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.908); catalogued as rs764581468; called by muse, mutect2, varscan2
- OR4C13 | c.320G>A p.G107D | Missense Mutation (SNP) | VAF 94/596 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.883); catalogued as rs782088918; called by muse, mutect2, varscan2
- OR4E1 | c.83G>A p.R28Q | Missense Mutation (SNP) | VAF 87/714 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs573199410; called by muse, mutect2, varscan2
- OR4M1 | c.803C>T p.S268F | Missense Mutation (SNP) | VAF 122/1652 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV60059391; called by muse, mutect2
- OR51B4 | c.904C>T p.R302C | Missense Mutation (SNP) | VAF 28/507 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as rs754916789, COSV66517085, COSV66517243; called by muse, mutect2
- OR51B4 | c.304C>T p.H102Y | Missense Mutation (SNP) | VAF 81/605 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV66517315; called by muse, mutect2, varscan2
- OR52E5 | c.761C>T p.A254V | Missense Mutation (SNP) | VAF 68/704 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.075); catalogued as rs1260428836; called by muse, mutect2, varscan2
- OR52J3 | c.518C>T p.A173V | Missense Mutation (SNP) | VAF 78/693 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.11); catalogued as rs368499772; called by muse, mutect2, varscan2
- OR8D1 | c.610G>A p.G204R | Missense Mutation (SNP) | VAF 81/520 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs754548110, COSV100766649, COSV63442430; called by muse, mutect2, varscan2
- OR8J3 | c.879G>T p.R293S | Missense Mutation (SNP) | VAF 54/521 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.081); catalogued as COSV56880768; called by muse, mutect2, varscan2
- OR9A4 | c.904C>T p.R302W | Missense Mutation (SNP) | VAF 37/1262 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as rs1379052061, COSV71886052; called by muse, mutect2
- OR9Q1 | c.12G>A p.M4I | Missense Mutation (SNP) | VAF 47/657 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV59038400; called by muse, mutect2
- OSBPL7 | c.484C>T p.P162S | Missense Mutation (SNP) | VAF 53/524 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV50107800; called by muse, mutect2, varscan2
- OTOF | c.4735G>A p.D1579N (on ENST00000272371 / NM_194248.3; = p.D812N on NM_004802.4) | Missense Mutation (SNP) | VAF 192/996 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs772890703; called by muse, mutect2, varscan2
- OTOG | c.1169G>A p.R390Q | Missense Mutation (SNP) | VAF 36/754 reads (5%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.984); catalogued as rs1051708966, COSV68038596; called by muse, mutect2
- OTOGL | c.4646G>A p.G1549E (on ENST00000547103; = p.G1540E on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 82/697 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54012956; called by muse, mutect2, varscan2
- OTUD3 | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 158/1175 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.111); catalogued as rs569453344; called by muse, mutect2, varscan2
- P2RX2 | c.1103C>T p.S368F | Missense Mutation (SNP) | VAF 312/1028 reads (30%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs746294218; called by muse, mutect2, varscan2
- PACS2 | c.182C>T p.S61F | Missense Mutation (SNP) | VAF 61/552 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as COSV57652765; called by muse, mutect2, varscan2
- PALMD | c.989G>A p.R330Q | Missense Mutation (SNP) | VAF 83/705 reads (12%) | SIFT tolerated (0.53); PolyPhen benign (0.207); catalogued as rs556174782, COSV54163638; called by muse, mutect2, varscan2
- PCDHA12 | c.1100C>T p.T367I | Missense Mutation (SNP) | VAF 143/933 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.979); catalogued as COSV100253553; called by muse, mutect2, varscan2
- PCDHA8 | c.101C>T p.S34F | Missense Mutation (SNP) | VAF 100/950 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.111); catalogued as COSV100970908; called by muse, varscan2
- PCDHA8 | c.1451C>T p.A484V | Missense Mutation (SNP) | VAF 98/1384 reads (7%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.23); catalogued as COSV65325316; called by muse, mutect2
- PCDHB9 | c.1808C>T p.S603L | Missense Mutation (SNP) | VAF 189/1086 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.909); catalogued as rs1185611634; called by muse, mutect2, varscan2
- PCDHGB1 | c.185G>A p.R62Q | Missense Mutation (SNP) | VAF 82/696 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.826); catalogued as COSV53959666; called by muse, varscan2
- PCDHGB5 | c.1375G>A p.E459K | Missense Mutation (SNP) | VAF 67/922 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1162604344; called by muse, mutect2
- PCLO | c.8896C>T p.R2966C | Missense Mutation (SNP) | VAF 104/906 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1173009964, COSV61649863; called by muse, mutect2, varscan2
- PCNX3 | c.1060C>T p.P354S | Missense Mutation (SNP) | VAF 79/1102 reads (7%) | SIFT tolerated (0.4); PolyPhen benign (0.067); catalogued as COSV58421198; called by muse, mutect2
- PCSK5 | c.1287G>A p.W429* | Nonsense Mutation (SNP) | VAF 221/795 reads (28%) | catalogued as COSV65084020; called by muse, mutect2, varscan2
- PDE4DIP | c.3850G>A p.E1284K | Missense Mutation (SNP) | VAF 20/627 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1173053585, COSV57676609; called by muse, mutect2
- PDGFC | c.1000G>A p.E334K | Missense Mutation (SNP) | VAF 84/598 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.26); catalogued as rs775498616; called by muse, mutect2, varscan2
- PDIK1L | c.896C>T p.S299F | Missense Mutation (SNP) | VAF 60/616 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.722); catalogued as COSV65322487; called by muse, mutect2
- PDZRN4 | c.2667G>A p.W889* (on ENST00000402685 / NM_001164595.2; = p.W631* on NM_013377.4) | Nonsense Mutation (SNP) | VAF 62/832 reads (7%) | catalogued as COSV100114987; called by muse, mutect2
- PER3 | c.1987C>T p.P663S | Missense Mutation (SNP) | VAF 173/748 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.056); catalogued as rs754474032; called by muse, mutect2, varscan2
- PER3 | c.1988C>T p.P663L | Missense Mutation (SNP) | VAF 174/754 reads (23%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.468); catalogued as rs764793226, COSV100728238; called by muse, mutect2, varscan2
- PGR | c.2158C>T p.Q720* | Nonsense Mutation (SNP) | VAF 66/660 reads (10%) | catalogued as COSV54798286; called by muse, mutect2
- PKHD1L1 | c.5492C>T p.P1831L | Missense Mutation (SNP) | VAF 80/780 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.147); catalogued as rs1330376459, COSV101005171, COSV65753827; called by muse, mutect2, varscan2
- PLG | c.1339G>A p.E447K | Missense Mutation (SNP) | VAF 65/556 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV51985104; called by muse, mutect2, varscan2
- PODNL1 | c.119C>T p.P40L | Missense Mutation (SNP) | VAF 166/911 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs780652527; called by muse, mutect2, varscan2
- POFUT2 | c.611C>T p.P204L | Missense Mutation (SNP) | VAF 161/717 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs1451764141; called by muse, mutect2, varscan2
- POLQ | c.3883A>G p.T1295A | Missense Mutation (SNP) | VAF 68/714 reads (10%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.021); catalogued as rs1329145039; called by muse, mutect2
- POLQ | c.2392C>T p.R798W | Missense Mutation (SNP) | VAF 125/835 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as rs753866746, COSV51748341, COSV51749862; called by muse, mutect2, varscan2
- PRAMEF20 | c.881C>T p.S294L | Missense Mutation (SNP) | VAF 64/224 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.36); catalogued as rs1426476885; called by muse, mutect2, varscan2
- PRDM16 | c.3708G>A p.M1236I | Missense Mutation (SNP) | VAF 39/770 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.035); catalogued as rs550550637; called by muse, mutect2
- PRDM9 | c.394G>A p.E132K | Missense Mutation (SNP) | VAF 67/534 reads (13%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.001); catalogued as COSV57002253, COSV57005862; called by muse, mutect2, varscan2
- PRR15 | c.193C>T p.L65F | Missense Mutation (SNP) | VAF 305/1227 reads (25%) | SIFT tolerated (0.37); PolyPhen benign (0.014); catalogued as rs761107881, COSV60501940; called by muse, mutect2, varscan2
- PRR36 | c.1999C>T p.P667S | Missense Mutation (SNP) | VAF 184/771 reads (24%) | SIFT deleterious, low confidence (0.03); catalogued as rs565768972; called by muse, mutect2, varscan2
- PRUNE2 | c.8301G>A p.M2767I | Missense Mutation (SNP) | VAF 271/942 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs868221532; called by muse, mutect2, varscan2
- PRUNE2 | c.5935G>A p.E1979K | Missense Mutation (SNP) | VAF 88/933 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.335); catalogued as rs750443357, COSV65043953; called by muse, mutect2
- PSME4 | c.5179C>T p.H1727Y | Missense Mutation (SNP) | VAF 83/656 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.242); catalogued as COSV66363163; called by muse, mutect2, varscan2
- PTAFR | c.979G>A p.E327K | Missense Mutation (SNP) | VAF 63/496 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.086); catalogued as rs141815776; called by muse, mutect2, varscan2
- PTCRA | c.191C>T p.S64L | Missense Mutation (SNP) | VAF 150/1058 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1424221749; called by muse, mutect2, varscan2
- PTH1R | c.1609C>T p.H537Y | Missense Mutation (SNP) | VAF 102/1501 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57314562; called by muse, mutect2
- PTPN21 | c.2009C>T p.S670L | Missense Mutation (SNP) | VAF 140/1077 reads (13%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as rs1278491535; called by muse, mutect2, varscan2
- PTPRC | c.3236G>A p.G1079E | Missense Mutation (SNP) | VAF 35/585 reads (6%) | SIFT tolerated (0.57); PolyPhen benign (0.127); catalogued as COSV61406961; called by muse, mutect2
- PTPRD | c.1657G>A p.D553N | Missense Mutation (SNP) | VAF 117/539 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.21); catalogued as rs750349056; called by muse, mutect2, varscan2
- PTPRT | c.2849G>A p.G950E | Missense Mutation (SNP) | VAF 77/835 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62012566; called by muse, mutect2
- PTPRT | c.1397A>G p.N466S | Missense Mutation (SNP) | VAF 188/921 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.918); catalogued as COSV62031466; called by muse, mutect2, varscan2
- PUS7L | c.815C>T p.P272L | Missense Mutation (SNP) | VAF 220/704 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as rs745790601, COSV61261378; called by muse, mutect2, varscan2
- PXDNL | c.842G>A p.R281Q | Missense Mutation (SNP) | VAF 69/568 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.782); catalogued as rs764492998, COSV62484203; called by muse, mutect2, varscan2
- RAC1 | c.85C>G p.P29A | Missense Mutation (SNP) | VAF 140/613 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.779); catalogued as COSV61821563, COSV61823187; called by muse, mutect2, varscan2
- RAPGEF4 | c.883G>A p.E295K | Missense Mutation (SNP) | VAF 122/762 reads (16%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.459); catalogued as rs540212267, COSV99909552; called by muse, mutect2, varscan2
- RBM26 | c.296C>T p.P99L | Missense Mutation (SNP) | VAF 104/496 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs1003266669; called by muse, mutect2, varscan2
- RGS3 | c.1520G>A p.G507E (on ENST00000350696 / NM_001282923.2; = p.G395E on NM_017790.4) | Missense Mutation (SNP) | VAF 235/892 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.706); catalogued as COSV58286331; called by muse, mutect2, varscan2
- RIDA | c.313C>T p.P105S | Missense Mutation (SNP) | VAF 96/513 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54704656; called by muse, mutect2, varscan2
- RIMBP2 | c.2116G>A p.E706K | Missense Mutation (SNP) | VAF 138/876 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.532); catalogued as rs774346465, COSV55480309; called by muse, mutect2, varscan2
- RIPOR3 | c.1514G>A p.R505K | Missense Mutation (SNP) | VAF 192/946 reads (20%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as COSV50399741; called by muse, mutect2, varscan2
- RORB | c.1085C>T p.S362F (on ENST00000396204 / NM_001365023.1; = p.S351F on NM_006914.4) | Missense Mutation (SNP) | VAF 85/664 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.389); catalogued as COSV65333458; called by muse, mutect2, varscan2
- RSPH6A | c.1297G>A p.E433K | Missense Mutation (SNP) | VAF 125/836 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.468); catalogued as rs760080479, COSV55572020; called by muse, mutect2, varscan2
- RTN1 | c.824C>T p.P275L | Missense Mutation (SNP) | VAF 115/743 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.109); catalogued as rs1411341807; called by muse, mutect2, varscan2
- RTN4RL1 | c.157C>T p.P53S | Missense Mutation (SNP) | VAF 293/942 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV58676768; called by muse, mutect2, varscan2
- RTTN | c.1483G>A p.E495K | Missense Mutation (SNP) | VAF 39/427 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs200326656; called by muse, mutect2
- SACS | c.9388C>T p.H3130Y | Missense Mutation (SNP) | VAF 29/528 reads (5%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.891); catalogued as COSV66536994; called by muse, mutect2
- SALL3 | c.589G>A p.V197M | Missense Mutation (SNP) | VAF 228/1288 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.089); catalogued as rs1384399552; called by muse, mutect2, varscan2
- SAMD9 | c.1663C>T p.P555S | Missense Mutation (SNP) | VAF 150/674 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs780430573, COSV66073396; called by muse, mutect2, varscan2
- SCAP | c.346C>T p.R116C | Missense Mutation (SNP) | VAF 45/886 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768447765, COSV55560369; called by muse, mutect2
- SCN10A | c.4660C>T p.L1554= | Splice Region (SNP) | VAF 26/276 reads (9%) | catalogued as rs745999522, COSV71862046; ClinVar: likely benign; called by muse, mutect2
- SCN1A | c.1341G>A p.M447I | Missense Mutation (SNP) | VAF 53/494 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.48); catalogued as COSV57662622, COSV57668099; called by muse, mutect2, varscan2
- SDR42E1 | c.275G>A p.R92Q | Missense Mutation (SNP) | VAF 128/737 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.059); catalogued as rs759669365, COSV61093955; called by muse, mutect2, varscan2
- SEMA6B | c.751G>A p.E251K | Missense Mutation (SNP) | VAF 41/781 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); catalogued as COSV100015049; called by muse, mutect2
- SERPINB4 | c.729G>A p.M243I | Missense Mutation (SNP) | VAF 110/674 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61985829; called by muse, mutect2, varscan2
- SET | c.787G>A p.E263K (on ENST00000372692 / NM_001374326.1; = p.E250K on NM_003011.4) | Missense Mutation (SNP) | VAF 304/974 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.084); catalogued as rs1013644374, COSV59002635; called by muse, varscan2
- SETD1B | c.758C>T p.S253F | Missense Mutation (SNP) | VAF 141/1133 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1421252638; called by muse, mutect2, varscan2
- SF3B2 | c.791C>T p.S264F | Missense Mutation (SNP) | VAF 44/406 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.243); catalogued as COSV59430570; called by muse, mutect2, varscan2
- SHISA6 | c.1126C>T p.R376W (on ENST00000409168 / NM_001173461.1; = p.R427W on NM_207386.4) | Missense Mutation (SNP) | VAF 253/956 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as rs1303790169; called by muse, mutect2, varscan2
- SKIDA1 | c.151C>T p.H51Y | Missense Mutation (SNP) | VAF 79/710 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1564335755; called by muse, mutect2, varscan2
- SKIV2L | c.1587G>A p.M529I | Missense Mutation (SNP) | VAF 156/1169 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs766951489; called by muse, mutect2, varscan2
- SLC15A4 | c.1523C>T p.A508V | Missense Mutation (SNP) | VAF 138/760 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.15); catalogued as COSV57163306; called by muse, mutect2, varscan2
- SLC16A12 | c.267G>A p.W89* | Nonsense Mutation (SNP) | VAF 122/591 reads (21%) | catalogued as COSV57954634, COSV57955481; called by muse, mutect2, varscan2
- SLC22A10 | c.629C>T p.S210F | Missense Mutation (SNP) | VAF 71/620 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.033); catalogued as COSV60423791; called by muse, mutect2, varscan2
- SLC22A25 | c.1582C>T p.Q528* | Nonsense Mutation (SNP) | VAF 72/549 reads (13%) | catalogued as rs747855832; called by muse, mutect2, varscan2
- SLC25A1 | c.629G>A p.R210Q | Missense Mutation (SNP) | VAF 161/602 reads (27%) | SIFT tolerated (0.46); PolyPhen benign (0.015); catalogued as rs148734543; called by muse, mutect2, varscan2
- SLC25A13 | c.102C>G p.F34L | Missense Mutation (SNP) | VAF 46/848 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV99674131; called by muse, mutect2
- SLC25A21 | c.186G>A p.M62I | Missense Mutation (SNP) | VAF 53/458 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV100490703; called by muse, mutect2, varscan2
- SLC2A11 | c.224C>T p.P75L (on ENST00000345044 / NM_001024938.4; = p.P82L on NM_030807.5) | Missense Mutation (SNP) | VAF 144/1336 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.115); catalogued as rs776326696, COSV99741428; called by muse, mutect2, varscan2
- SLC4A5 | c.1909G>A p.E637K | Missense Mutation (SNP) | VAF 212/1071 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1044766943, COSV100698183; called by muse, mutect2, varscan2
- SLCO6A1 | c.412C>T p.Q138* | Nonsense Mutation (SNP) | VAF 170/880 reads (19%) | catalogued as rs1561496268; called by muse, mutect2, varscan2
- SLITRK1 | c.1148G>A p.R383Q | Missense Mutation (SNP) | VAF 111/783 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.594); catalogued as COSV65675264; called by muse, mutect2, varscan2
- SMTN | c.1837C>T p.R613C | Missense Mutation (SNP) | VAF 273/927 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs147067065; called by muse, mutect2, varscan2
- SORBS2 | c.1273C>T p.P425S | Missense Mutation (SNP) | VAF 83/729 reads (11%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.001); catalogued as rs769209264; called by muse, mutect2, varscan2
- SORCS3 | c.152C>T p.S51L | Missense Mutation (SNP) | VAF 167/973 reads (17%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.028); catalogued as rs1248897947; called by muse, mutect2, varscan2
- SORL1 | c.2629C>T p.R877C | Missense Mutation (SNP) | VAF 102/627 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs769806986, COSV52762752; called by muse, mutect2, varscan2
- SORL1 | c.3250C>T p.R1084C | Missense Mutation (SNP) | VAF 56/515 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as COSV52757172; called by muse, mutect2, varscan2
- SPAG17 | c.5491G>A p.E1831K | Missense Mutation (SNP) | VAF 17/397 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV60464558; called by muse, mutect2
- SPANXN2 | c.194C>T p.S65L | Missense Mutation (SNP) | VAF 184/522 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV65129244; called by muse, mutect2, varscan2
- SPATA16 | c.1348C>T p.P450S | Missense Mutation (SNP) | VAF 23/469 reads (5%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV63528247; called by muse, mutect2
- SPATA31D1 | c.2863G>A p.D955N | Missense Mutation (SNP) | VAF 101/926 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.078); catalogued as rs764094298, COSV100783112; called by muse, mutect2, varscan2
- SPATA48 | c.1228C>T p.R410C | Missense Mutation (SNP) | VAF 192/695 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.799); catalogued as rs776445042; called by muse, mutect2, varscan2
- SPTB | c.2464C>T p.R822W | Missense Mutation (SNP) | VAF 212/1067 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as rs201338747, COSV101071991, COSV67630731; called by muse, mutect2, varscan2
- SRGAP3 | c.2273G>A p.R758Q | Missense Mutation (SNP) | VAF 85/1003 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); catalogued as rs1230085280, COSV64537324; called by muse, mutect2
- SRRM2 | c.7643C>T p.S2548L | Missense Mutation (SNP) | VAF 168/895 reads (19%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.968); catalogued as rs1489992111; called by muse, mutect2, varscan2
- SSTR1 | c.91G>A p.G31R | Missense Mutation (SNP) | VAF 140/1164 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0.201); catalogued as rs956946782; called by muse, mutect2, varscan2
- ST14 | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 63/515 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.866); catalogued as rs754002164; called by muse, mutect2, varscan2
- STK11 | c.1151G>A p.R384Q | Missense Mutation (SNP) | VAF 49/1085 reads (5%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as rs371102112; ClinVar: uncertain significance; called by muse, mutect2
- STK11IP | c.922C>T p.R308W | Missense Mutation (SNP) | VAF 111/832 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs376333597; called by muse, mutect2, varscan2
- STK11IP | c.3001C>T p.P1001S | Missense Mutation (SNP) | VAF 52/1024 reads (5%) | SIFT tolerated (0.49); PolyPhen benign (0.018); catalogued as rs1373448855, COSV55253313; called by muse, mutect2
- STK11IP | c.3002C>T p.P1001L | Missense Mutation (SNP) | VAF 54/1032 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.011); catalogued as rs1218566670; called by muse, mutect2
- STK33 | c.409G>A p.E137K | Missense Mutation (SNP) | VAF 150/782 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.288); catalogued as rs867053141, COSV59396711; called by muse, mutect2
- STOML3 | c.577G>A p.D193N | Missense Mutation (SNP) | VAF 66/889 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.942); catalogued as COSV65510198; called by muse, mutect2
- SUPT16H | c.3005G>A p.R1002Q | Missense Mutation (SNP) | VAF 63/437 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.885); catalogued as rs1398232340; called by muse, mutect2, varscan2
- SYDE1 | c.1823A>G p.Q608R | Missense Mutation (SNP) | VAF 84/709 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs762867875; called by muse, mutect2, varscan2
- TARS2 | c.839C>T p.S280F | Missense Mutation (SNP) | VAF 97/620 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV64696677; called by muse, mutect2, varscan2
- TBX3 | c.1786C>T p.P596S (on ENST00000257566 / NM_016569.4; = p.P576S on NM_005996.4) | Missense Mutation (SNP) | VAF 116/811 reads (14%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.505); catalogued as rs1437311804, COSV57470559; called by muse, mutect2, varscan2
- TDRD15 | c.446G>A p.G149E | Missense Mutation (SNP) | VAF 60/543 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs1300893253; called by muse, mutect2, varscan2
- TENM1 | c.5443C>T p.R1815* | Nonsense Mutation (SNP) | VAF 48/494 reads (10%) | catalogued as rs1453916240, COSV64442614; called by muse, mutect2, varscan2
- TENM3 | c.2980G>A p.E994K | Missense Mutation (SNP) | VAF 59/408 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as COSV69311860; called by muse, mutect2, varscan2
- TEP1 | c.1619C>T p.S540F | Missense Mutation (SNP) | VAF 83/584 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.12); catalogued as COSV99402504; called by muse, mutect2, varscan2
- TFAP4 | c.730C>T p.P244S | Missense Mutation (SNP) | VAF 86/665 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.059); catalogued as COSV52597177; called by muse, mutect2, varscan2
- TFF1 | c.37G>A p.V13I | Missense Mutation (SNP) | VAF 52/768 reads (7%) | SIFT tolerated (0.44); PolyPhen benign (0.079); catalogued as rs1192324357; called by muse, mutect2
- THBS2 | c.2584G>A p.E862K | Missense Mutation (SNP) | VAF 116/656 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as rs1471486124, COSV104422514; called by muse, mutect2, varscan2
- THRB | c.620C>T p.S207F | Missense Mutation (SNP) | VAF 72/1148 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.336); catalogued as rs1442067759; called by muse, mutect2
- TLE2 | c.761C>T p.P254L | Missense Mutation (SNP) | VAF 150/855 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs746239008, COSV53581022; called by muse, varscan2
- TLE3 | c.935C>T p.T312I | Missense Mutation (SNP) | VAF 115/659 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.196); catalogued as rs1363080419; called by muse, mutect2, varscan2
- TLE6 | c.1417G>A p.D473N (on ENST00000246112 / NM_001143986.2; = p.D350N on NM_024760.3) | Missense Mutation (SNP) | VAF 82/637 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs764729766; called by muse, mutect2, varscan2
- TMC5 | c.18G>T p.R6S | Missense Mutation (SNP) | VAF 107/428 reads (25%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.001); catalogued as COSV66867077; called by muse, mutect2, varscan2
- TMEM132C | c.1507G>T p.D503Y | Missense Mutation (SNP) | VAF 77/719 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.861); catalogued as COSV100176137, COSV59412998; called by muse, mutect2, varscan2
- TMEM132D | c.122C>T p.S41F | Missense Mutation (SNP) | VAF 44/775 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV70596931; called by muse, mutect2
- TMEM176A | c.127C>T p.R43W | Missense Mutation (SNP) | VAF 118/1932 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.183); catalogued as rs748267918, COSV50243456; called by muse, mutect2
- TMEM222 | c.16G>A p.G6R | Missense Mutation (SNP) | VAF 115/775 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as rs1447120807, COSV65027134; called by muse, mutect2, varscan2
- TMEM259 | c.1289C>T p.A430V | Missense Mutation (SNP) | VAF 78/790 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.845); catalogued as rs374342292; called by muse, mutect2
- TNFRSF11A | c.715G>A p.G239R | Missense Mutation (SNP) | VAF 68/556 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99500024; called by muse, mutect2, varscan2
- TP53BP2 | c.1385C>T p.P462L (on ENST00000343537 / NM_001031685.3; = p.P333L on NM_005426.2) | Missense Mutation (SNP) | VAF 53/773 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs774631779; called by muse, mutect2
- TRAV4 | c.244C>T p.P82S | Missense Mutation (SNP) | VAF 67/655 reads (10%) | SIFT tolerated (0.56); PolyPhen benign (0.005); catalogued as rs372255405; called by muse, mutect2, varscan2
- TRBV4-2 | c.97G>A p.G33R | Missense Mutation (SNP) | VAF 480/1528 reads (31%) | SIFT tolerated (0.37); PolyPhen benign (0.115); catalogued as rs369148483; called by muse, mutect2, varscan2
- TRIM71 | c.1967C>T p.P656L | Missense Mutation (SNP) | VAF 219/911 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67472413; called by muse, mutect2, varscan2
- TRMT9B | c.1139C>T p.S380F | Missense Mutation (SNP) | VAF 257/734 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as rs1329855130; called by muse, mutect2, varscan2
- TRPM8 | c.118-1G>A p.X40_splice | Splice Site (SNP) | VAF 34/501 reads (7%) | catalogued as COSV100224758, COSV61223445; called by muse, mutect2
- TRPM8 | c.118G>A p.D40N | Missense Mutation (SNP) | VAF 34/508 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV61221900; called by muse, mutect2
- TSHZ2 | c.1882C>T p.H628Y | Missense Mutation (SNP) | VAF 102/1292 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs1163720906; called by muse, mutect2
- TTC3 | c.2770C>T p.R924C | Missense Mutation (SNP) | VAF 75/499 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs376428095; called by muse, mutect2, varscan2
- TTLL12 | c.1493G>A p.R498Q | Missense Mutation (SNP) | VAF 299/816 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.111); catalogued as rs756238086; called by muse, mutect2, varscan2
- TTN | c.63766C>T p.P21256S (on ENST00000591111; = p.P13832S on NM_003319.4) | Missense Mutation (SNP) | VAF 58/1090 reads (5%) | PolyPhen benign (0.058); catalogued as rs749642221; called by muse, mutect2
- TTN | c.42770G>A p.R14257Q (on ENST00000591111; = p.R6833Q on NM_003319.4) | Missense Mutation (SNP) | VAF 150/704 reads (21%) | PolyPhen benign (0.387); catalogued as rs376278449; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.35206G>A p.E11736K (on ENST00000591111; = p.E10809K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 52/727 reads (7%) | catalogued as rs1203876644, COSV60172972; called by muse, mutect2
- TTN | c.10390G>A p.E3464K (on ENST00000591111; = p.E3418K on NM_003319.4) | Missense Mutation (SNP) | VAF 127/432 reads (29%) | catalogued as rs773793548, COSV59961451; called by muse, mutect2, varscan2
- U2AF1L4 | c.533C>T p.S178F (on ENST00000412391; = p.P120S on NM_144987.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 82/643 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1368698729; called by muse, mutect2, varscan2
- UBASH3A | c.140G>A p.R47K | Missense Mutation (SNP) | VAF 114/668 reads (17%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs535815573; called by muse, varscan2
- UBR5 | c.2563C>T p.P855S | Missense Mutation (SNP) | VAF 92/723 reads (13%) | SIFT tolerated (1); PolyPhen probably damaging (0.968); catalogued as COSV99640590; called by muse, mutect2, varscan2
- UBTFL1 | c.356C>T p.S119F | Missense Mutation (SNP) | VAF 84/580 reads (14%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.924); catalogued as COSV73297846; called by muse, mutect2, varscan2
- UBXN4 | c.967C>T p.Q323* | Nonsense Mutation (SNP) | VAF 54/506 reads (11%) | catalogued as COSV99739362; called by muse, mutect2, varscan2
- UGGT1 | c.2697C>T p.I899= | Splice Region (SNP) | VAF 92/383 reads (24%) | catalogued as COSV52132700; called by muse, mutect2, varscan2
- UNC80 | c.619C>T p.R207C | Missense Mutation (SNP) | VAF 67/489 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as rs904613800, COSV99781352; called by muse, mutect2, varscan2
- UNC80 | c.3628G>A p.D1210N | Missense Mutation (SNP) | VAF 30/536 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV55889602; called by muse, mutect2
- UNG | c.832C>T p.P278S (on ENST00000242576 / NM_080911.3; = p.P269S on NM_003362.4) | Missense Mutation (SNP) | VAF 38/775 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1395194695, COSV54356571; called by muse, mutect2
- UROC1 | c.1946C>T p.T649I | Missense Mutation (SNP) | VAF 169/780 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.261); catalogued as COSV52038233; called by muse, mutect2, varscan2
- USP29 | c.2734G>A p.E912K | Missense Mutation (SNP) | VAF 61/578 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as COSV54143461; called by muse, mutect2, varscan2
- WDR97 | c.3674G>A p.R1225H | Missense Mutation (SNP) | VAF 296/1211 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.849); catalogued as rs1010272017; called by muse, mutect2, varscan2
- WFIKKN2 | c.1015G>A p.E339K | Missense Mutation (SNP) | VAF 51/1009 reads (5%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.472); catalogued as rs753365907; called by muse, mutect2
- WNK2 | c.5458G>A p.D1820N (on ENST00000297954 / NM_001282394.1; = p.D1783N on NM_006648.3) | Missense Mutation (SNP) | VAF 488/1512 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.913); catalogued as rs534820585; called by muse, mutect2, varscan2
- XIRP2 | c.9905G>A p.R3302K (on ENST00000628543; = p.R3477K on NM_152381.6) | Missense Mutation (SNP) | VAF 60/834 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV54692278; called by muse, mutect2
- XKR3 | c.316C>T p.L106F | Missense Mutation (SNP) | VAF 134/413 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as COSV58887545; called by muse, mutect2, varscan2
- XKR7 | c.585-1G>A p.X195_splice | Splice Site (SNP) | VAF 66/906 reads (7%) | catalogued as rs6061078; called by muse, mutect2
- ZAN | c.1443G>A p.W481* | Nonsense Mutation (SNP) | VAF 249/1155 reads (22%) | catalogued as COSV61810566; called by muse, mutect2, varscan2
- ZAN | c.1639C>T p.P547S | Missense Mutation (SNP) | VAF 165/830 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.962); catalogued as COSV61806608; called by muse, mutect2, varscan2
- ZBED9 | c.3110G>A p.R1037K | Missense Mutation (SNP) | VAF 62/540 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.745); catalogued as COSV71729756; called by muse, mutect2, varscan2
- ZDBF2 | c.4462G>A p.E1488K | Missense Mutation (SNP) | VAF 122/651 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.307); catalogued as COSV65625608; called by muse, mutect2, varscan2
- ZDHHC4 | c.904C>T p.P302S | Missense Mutation (SNP) | VAF 305/1003 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.348); catalogued as rs528731551; called by muse, mutect2, varscan2
- ZFP64 | c.1369G>A p.D457N | Missense Mutation (SNP) | VAF 210/1032 reads (20%) | SIFT tolerated (0.61); PolyPhen benign (0.272); catalogued as COSV53801284, COSV99402030; called by muse, mutect2, varscan2
- ZMYM4 | c.1588C>T p.P530S | Missense Mutation (SNP) | VAF 63/488 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs1318149646, COSV58909410; called by muse, mutect2, varscan2
- ZNF17 | c.1138C>T p.H380Y | Missense Mutation (SNP) | VAF 121/793 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56920821; called by muse, mutect2, varscan2
- ZNF304 | c.322C>T p.Q108* | Nonsense Mutation (SNP) | VAF 113/840 reads (13%) | catalogued as rs1287081247; called by muse, mutect2, varscan2
- ZNF334 | c.989T>G p.F330C | Missense Mutation (SNP) | VAF 108/918 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61619638; called by mutect2, varscan2
- ZNF423 | c.2995C>T p.R999C (on ENST00000563137 / NM_001379286.1; = p.R991C on NM_015069.4) | Missense Mutation (SNP) | VAF 97/621 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); catalogued as rs1286832424, COSV52186046; called by muse, mutect2, varscan2
- ZNF451 | c.469C>T p.R157* | Nonsense Mutation (SNP) | VAF 146/677 reads (22%) | catalogued as rs752623979, COSV62600202; called by muse, mutect2, varscan2
- ZNF543 | c.764A>G p.Y255C | Missense Mutation (SNP) | VAF 76/641 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs758350147, COSV58627492; called by muse, mutect2, varscan2
- ZNF556 | c.911G>A p.R304Q | Missense Mutation (SNP) | VAF 98/795 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.091); catalogued as rs542573466, COSV56910771; called by muse, mutect2, varscan2
- ZNF567 | c.1579C>T p.H527Y (on ENST00000536254 / NM_001322913.1; = p.H496Y on NM_152603.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 71/592 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV62446736; called by muse, mutect2, varscan2
- ZNF583 | c.968C>T p.P323L | Missense Mutation (SNP) | VAF 99/843 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52401594; called by muse, mutect2, varscan2
- ZNF598 | c.619C>T p.R207C | Missense Mutation (SNP) | VAF 175/707 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745564530; called by muse, mutect2, varscan2
- ZNF654 | c.749G>A p.R250Q | Missense Mutation (SNP) | VAF 108/420 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1440851783; called by muse, mutect2, varscan2
- ZNF668 | c.1139C>T p.T380M | Missense Mutation (SNP) | VAF 159/1115 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.438); catalogued as rs1046648741, COSV56218317; called by muse, mutect2, varscan2
- ZNF71 | c.184C>T p.P62S | Missense Mutation (SNP) | VAF 145/828 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1253817718; called by muse, mutect2, varscan2
- ZNF716 | c.662C>T p.S221F | Missense Mutation (SNP) | VAF 48/968 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV70779105; called by muse, mutect2
- ZNF768 | c.1160C>T p.S387F | Missense Mutation (SNP) | VAF 229/956 reads (24%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.96); catalogued as COSV104416766; called by muse, mutect2, varscan2
- ZNF787 | c.797C>T p.A266V | Missense Mutation (SNP) | VAF 85/474 reads (18%) | SIFT tolerated (0.43); PolyPhen benign (0.081); catalogued as rs1362725280; called by muse, mutect2, varscan2
- AASS | c.646C>T p.P216S | Missense Mutation (SNP) | VAF 112/892 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- ABCA1 | c.3208G>A p.G1070R | Missense Mutation (SNP) | VAF 86/870 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.027); called by muse, mutect2
- ABCA13 | c.11214G>A p.W3738* | Nonsense Mutation (SNP) | VAF 68/532 reads (13%) | called by muse, mutect2, varscan2
- ABCC9 | c.4201G>A p.G1401S | Missense Mutation (SNP) | VAF 25/597 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- AC092835.1 | c.1147C>G p.H383D | Missense Mutation (SNP) | VAF 81/720 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ACAD11 | c.2204C>T p.S735F | Missense Mutation (SNP) | VAF 72/648 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ACADS | c.463A>T p.S155C | Missense Mutation (SNP) | VAF 40/713 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- ACE | c.1584C>T p.I528= | Splice Region (SNP) | VAF 65/592 reads (11%) | called by muse, mutect2, varscan2
- ACKR2 | c.502G>A p.V168I | Missense Mutation (SNP) | VAF 46/887 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); called by muse, mutect2
- ACTL9 | c.616G>A p.V206M | Missense Mutation (SNP) | VAF 110/889 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- ACVR2B | c.815C>T p.S272F | Missense Mutation (SNP) | VAF 90/358 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ACY3 | c.911C>T p.T304I | Missense Mutation (SNP) | VAF 95/703 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ADAM32 | c.2029G>A p.G677R | Missense Mutation (SNP) | VAF 40/746 reads (5%) | SIFT tolerated (0.71); PolyPhen benign (0.001); called by muse, mutect2
- ADAMTS13 | c.670C>A p.H224N | Missense Mutation (SNP) | VAF 65/714 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ADCY2 | c.3007C>T p.H1003Y | Missense Mutation (SNP) | VAF 20/402 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- ADCY5 | c.2604G>C p.E868D | Missense Mutation (SNP) | VAF 65/1380 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.01); called by muse, mutect2
- ADGRA1 | c.976G>A p.D326N | Missense Mutation (SNP) | VAF 100/1237 reads (8%) | SIFT tolerated (0.77); PolyPhen benign (0.003); called by muse, mutect2
- ADGRB1 | c.977C>T p.S326F | Missense Mutation (SNP) | VAF 206/948 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- ADGRV1 | c.12038G>A p.R4013K | Missense Mutation (SNP) | VAF 92/856 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- AFF4 | c.1949C>G p.S650C | Missense Mutation (SNP) | VAF 38/650 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); called by muse, mutect2
- AHCYL1 | c.1547G>A p.G516E | Missense Mutation (SNP) | VAF 109/721 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AHNAK2 | c.2660C>T p.S887F | Missense Mutation (SNP) | VAF 127/1077 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- AKAP5 | c.500C>T p.T167I | Missense Mutation (SNP) | VAF 78/826 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.026); called by muse, mutect2
- AL645922.1 | c.1471C>T p.Q491* | Nonsense Mutation (SNP) | VAF 94/845 reads (11%) | called by muse, mutect2, varscan2
- ALOX15B | c.971G>A p.G324E | Missense Mutation (SNP) | VAF 69/838 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.733); called by muse, mutect2
- ALPL | c.1028G>A p.G343E | Missense Mutation (SNP) | VAF 100/745 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- AMZ1 | c.112C>T p.P38S | Missense Mutation (SNP) | VAF 327/1141 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ANK3 | c.7186G>A p.E2396K | Missense Mutation (SNP) | VAF 82/618 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.664); called by muse, mutect2, varscan2
- ANKRD18A | c.2854G>A p.E952K | Missense Mutation (SNP) | VAF 120/606 reads (20%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- ANKRD18A | c.1262C>T p.S421F | Missense Mutation (SNP) | VAF 277/848 reads (33%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- ANLN | c.2140G>C p.V714L | Missense Mutation (SNP) | VAF 63/500 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- ANO8 | c.2428G>A p.E810K | Missense Mutation (SNP) | VAF 68/478 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- AP2A1 | c.1579C>T p.H527Y | Missense Mutation (SNP) | VAF 81/674 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- AP3B1 | c.2561C>T p.S854F | Missense Mutation (SNP) | VAF 53/470 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- APBA1 | c.199G>A p.E67K | Missense Mutation (SNP) | VAF 251/1422 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.453); called by muse, mutect2, varscan2
- APC | c.7430C>T p.S2477F | Missense Mutation (SNP) | VAF 82/886 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- APC2 | c.1306G>A p.G436R | Missense Mutation (SNP) | VAF 44/722 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- API5 | c.231T>C p.S77= | Splice Region (SNP) | VAF 103/449 reads (23%) | called by muse, mutect2, varscan2
- API5 | c.965C>T p.P322L | Missense Mutation (SNP) | VAF 88/553 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARC | c.620C>T p.P207L | Missense Mutation (SNP) | VAF 143/1245 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.217); called by muse, mutect2, varscan2
- ARHGAP21 | c.1798C>T p.Q600* | Nonsense Mutation (SNP) | VAF 78/850 reads (9%) | called by muse, mutect2
- ARHGAP31 | c.4084C>T p.P1362S | Missense Mutation (SNP) | VAF 541/1243 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ARHGAP32 | c.5446G>C p.A1816P (on ENST00000310343 / NM_001378025.1; = p.A1467P on NM_014715.4) | Missense Mutation (SNP) | VAF 106/715 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARHGAP39 | c.1043C>T p.S348L | Missense Mutation (SNP) | VAF 96/917 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- ARHGAP39 | c.257G>A p.S86N | Missense Mutation (SNP) | VAF 272/1090 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.148); called by muse, mutect2, varscan2
- ARHGEF35 | c.1060G>A p.E354K | Missense Mutation (SNP) | VAF 58/2092 reads (3%) | SIFT tolerated (0.92); PolyPhen benign (0.001); called by muse, mutect2
- ARID1B | c.6518C>T p.P2173L | Missense Mutation (SNP) | VAF 182/799 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- ARID4B | c.1882G>A p.A628T | Missense Mutation (SNP) | VAF 19/526 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2
- ARPP21 | c.1217C>T p.S406F | Missense Mutation (SNP) | VAF 22/449 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2
- ASAH2 | c.1910del p.L637* | Frame Shift Del (DEL) | VAF 86/719 reads (12%) | called by mutect2, varscan2
- ASXL3 | c.3016G>A p.E1006K | Missense Mutation (SNP) | VAF 73/612 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- AXDND1 | c.1005-1G>A p.X335_splice | Splice Site (SNP) | VAF 22/296 reads (7%) | called by muse, mutect2
- B3GNT3 | c.1078C>T p.Q360* | Nonsense Mutation (SNP) | VAF 70/602 reads (12%) | called by muse, mutect2, varscan2
- BAHCC1 | c.2739G>C p.M913I | Missense Mutation (SNP) | VAF 289/1291 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- BCL11A | c.1031C>T p.S344L (on ENST00000335712 / NM_001365609.1; = p.S378L on NM_018014.4) | Missense Mutation (SNP) | VAF 83/662 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- BCL11A | c.607C>T p.P203S (on ENST00000335712 / NM_001365609.1; = p.P237S on NM_018014.4) | Missense Mutation (SNP) | VAF 108/777 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- BMP6 | c.971_973delinsG p.N324Sfs*43 | Frame Shift Del (DEL) | VAF 149/679 reads (22%) | called by pindel, varscan2*
- BMPR2 | c.1475T>G p.L492R | Missense Mutation (SNP) | VAF 93/730 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BRD9 | c.1661C>T p.S554F | Missense Mutation (SNP) | VAF 107/902 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- BUD23 | c.716T>A p.M239K | Missense Mutation (SNP) | VAF 158/682 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- C11orf87 | c.100G>A p.G34S | Missense Mutation (SNP) | VAF 86/1072 reads (8%) | SIFT tolerated, low confidence (0.84); PolyPhen benign (0); called by muse, mutect2
- C17orf97 | c.142T>C p.Y48H | Missense Mutation (SNP) | VAF 379/1158 reads (33%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- C1QTNF4 | c.785G>A p.G262D | Missense Mutation (SNP) | VAF 176/1052 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- C2CD3 | c.2296C>T p.P766S | Missense Mutation (SNP) | VAF 105/909 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- C2CD4C | c.67G>A p.G23S | Missense Mutation (SNP) | VAF 141/1162 reads (12%) | SIFT tolerated (0.84); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- C2orf16 | c.3242G>A p.G1081E | Missense Mutation (SNP) | VAF 87/550 reads (16%) | SIFT tolerated (1); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C3orf38 | c.294C>G p.Y98* | Nonsense Mutation (SNP) | VAF 40/738 reads (5%) | called by muse, mutect2
- C4orf17 | c.509C>T p.T170I | Missense Mutation (SNP) | VAF 105/539 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- C6orf226 | c.50C>T p.A17V | Missense Mutation (SNP) | VAF 230/918 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- C6orf58 | c.410C>T p.S137L | Missense Mutation (SNP) | VAF 95/494 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- C7 | c.1793C>A p.T598N | Missense Mutation (SNP) | VAF 71/558 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.688); called by muse, mutect2, varscan2
- C9orf135 | c.352G>A p.E118K | Missense Mutation (SNP) | VAF 75/732 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- CA9 | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 283/779 reads (36%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- CACNA1E | c.5333G>A p.G1778D | Missense Mutation (SNP) | VAF 95/656 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CAPRIN1 | c.1499C>T p.P500L | Missense Mutation (SNP) | VAF 102/940 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.265); called by muse, mutect2
- CBWD5 | c.1174C>T p.Q392* (on ENST00000382405 / NM_001330668.1; = p.Q344* on NM_001024916.3) | Nonsense Mutation (SNP) | VAF 132/1424 reads (9%) | called by muse, mutect2
- CCDC160 | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 138/383 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CCDC38 | c.320G>A p.R107K | Missense Mutation (SNP) | VAF 40/741 reads (5%) | SIFT tolerated (0.51); PolyPhen benign (0.003); called by muse, mutect2
- CCL4 | c.262G>A p.D88N | Missense Mutation (SNP) | VAF 95/866 reads (11%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.802); called by muse, mutect2, varscan2
- CD300LF | c.851A>G p.Y284C | Missense Mutation (SNP) | VAF 47/756 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CDC20B | c.1307G>A p.G436E | Missense Mutation (SNP) | VAF 79/425 reads (19%) | SIFT tolerated (0.54); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CDH8 | c.454G>A p.E152K | Missense Mutation (SNP) | VAF 106/713 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.568); called by muse, mutect2, varscan2
- CDS2 | c.809C>T p.T270I | Missense Mutation (SNP) | VAF 187/732 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CEMIP | c.1348C>T p.Q450* | Nonsense Mutation (SNP) | VAF 187/983 reads (19%) | called by muse, mutect2, varscan2
- CFAP65 | c.2087T>G p.F696C | Missense Mutation (SNP) | VAF 74/1084 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CHD7 | c.410C>T p.S137F | Missense Mutation (SNP) | VAF 121/908 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- CLIC5 | c.133G>A p.D45N | Missense Mutation (SNP) | VAF 110/879 reads (13%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CNOT6 | c.1108G>A p.D370N | Missense Mutation (SNP) | VAF 71/674 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL1A2 | c.209C>T p.P70L | Missense Mutation (SNP) | VAF 171/855 reads (20%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL22A1 | c.2420G>A p.G807E | Missense Mutation (SNP) | VAF 84/740 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL22A1 | c.2419G>A p.G807R | Missense Mutation (SNP) | VAF 84/740 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL3A1 | c.571C>T p.P191S | Missense Mutation (SNP) | VAF 88/735 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- COL4A3 | c.4120G>A p.E1374K | Missense Mutation (SNP) | VAF 42/634 reads (7%) | SIFT tolerated (0.37); PolyPhen benign (0.156); called by muse, mutect2
- COL6A3 | c.360A>T p.K120N | Missense Mutation (SNP) | VAF 36/678 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.187); called by muse, mutect2
- COL8A1 | c.1660G>A p.G554S | Missense Mutation (SNP) | VAF 135/895 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL9A2 | c.451C>T p.P151S | Missense Mutation (SNP) | VAF 114/827 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- CORIN | c.1148G>A p.G383D | Missense Mutation (SNP) | VAF 64/545 reads (12%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- CPA1 | c.259G>A p.E87K | Missense Mutation (SNP) | VAF 153/1439 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- CPEB2 | c.1919A>G p.N640S | Missense Mutation (SNP) | VAF 79/426 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.316); called by muse, mutect2, varscan2
- CROCC2 | c.670C>A p.P224T | Missense Mutation (SNP) | VAF 140/762 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.774); called by muse, mutect2, varscan2
- CRTC1 | c.1078T>C p.S360P | Missense Mutation (SNP) | VAF 90/877 reads (10%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- CSNKA2IP | c.1475G>A p.G492E | Missense Mutation (SNP) | VAF 164/637 reads (26%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CYP2C19 | c.439G>A p.E147K | Missense Mutation (SNP) | VAF 152/761 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.476); called by muse, mutect2, varscan2
- CYP4F12 | c.1391G>A p.G464E | Missense Mutation (SNP) | VAF 34/470 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CYTIP | c.935C>T p.S312F | Missense Mutation (SNP) | VAF 209/854 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- DBNL | c.20G>A p.R7Q | Missense Mutation (SNP) | VAF 148/947 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- DBX2 | c.532G>A p.D178N | Missense Mutation (SNP) | VAF 46/744 reads (6%) | SIFT tolerated (0.4); PolyPhen benign (0.439); called by muse, mutect2
- DCAF8L2 | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 220/603 reads (36%) | SIFT tolerated (0.44); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- DCHS1 | c.3854C>T p.P1285L | Missense Mutation (SNP) | VAF 90/543 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- DCHS1 | c.1115C>T p.S372F | Missense Mutation (SNP) | VAF 75/994 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.639); called by muse, mutect2
- DECR2 | c.826C>T p.P276S | Missense Mutation (SNP) | VAF 119/1065 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- DGKK | c.3104G>A p.R1035K | Missense Mutation (SNP) | VAF 76/257 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- DHX29 | c.630T>A p.Y210* | Nonsense Mutation (SNP) | VAF 71/534 reads (13%) | called by muse, varscan2
- DHX37 | c.698C>T p.P233L | Missense Mutation (SNP) | VAF 247/774 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- DICER1 | c.2126A>G p.D709G | Missense Mutation (SNP) | VAF 27/506 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2
- DIP2C | c.3225T>G p.I1075M | Missense Mutation (SNP) | VAF 117/596 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.803); called by muse, mutect2, varscan2
- DMRTC1 | c.566C>T p.S189F | Missense Mutation (SNP) | VAF 54/324 reads (17%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- DNAH1 | c.7367C>T p.A2456V | Missense Mutation (SNP) | VAF 115/549 reads (21%) | SIFT tolerated (0.35); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- DNAH1 | c.9158T>G p.V3053G | Missense Mutation (SNP) | VAF 166/672 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DNAH11 | c.12397G>C p.E4133Q | Missense Mutation (SNP) | VAF 60/566 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- DNAH12 | c.394G>A p.E132K | Missense Mutation (SNP) | VAF 48/882 reads (5%) | SIFT tolerated (0.61); PolyPhen benign (0); called by muse, mutect2
- DNAH7 | c.11162C>T p.S3721L | Missense Mutation (SNP) | VAF 46/922 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.062); called by muse, mutect2
- DNHD1 | c.8753G>T p.G2918V | Missense Mutation (SNP) | VAF 46/940 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.169); called by muse, mutect2
- DOP1B | c.4817C>T p.A1606V | Missense Mutation (SNP) | VAF 48/630 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- DSCAM | c.3900G>A p.M1300I | Missense Mutation (SNP) | VAF 125/554 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- DTL | c.1969C>T p.P657S | Missense Mutation (SNP) | VAF 89/561 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- EDA | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 110/401 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- EFNB3 | c.925C>T p.P309S | Missense Mutation (SNP) | VAF 350/1016 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, varscan2
- EGFLAM | c.1784G>A p.G595E | Missense Mutation (SNP) | VAF 48/426 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ELAVL4 | c.575G>A p.G192E | Missense Mutation (SNP) | VAF 76/626 reads (12%) | SIFT tolerated (0.73); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- ELMOD1 | c.685G>A p.D229N | Missense Mutation (SNP) | VAF 40/684 reads (6%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.596); called by muse, mutect2
- EP400 | c.4787G>A p.G1596D | Missense Mutation (SNP) | VAF 102/853 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EPB41L1 | c.2637G>A p.Q879= | Splice Region (SNP) | VAF 53/505 reads (10%) | called by muse, mutect2, varscan2
- EPHB2 | c.1600C>T p.Q534* | Nonsense Mutation (SNP) | VAF 68/616 reads (11%) | called by muse, mutect2, varscan2
- EPS15L1 | c.2546C>A p.P849H | Missense Mutation (SNP) | VAF 53/746 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2
- ERI2 | c.2033C>T p.S678F | Missense Mutation (SNP) | VAF 134/614 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.312); called by muse, mutect2, varscan2
- ESM1 | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 77/684 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.294); called by muse, mutect2, varscan2
- EXOC6B | c.14A>G p.K5R | Missense Mutation (SNP) | VAF 139/708 reads (20%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- F13A1 | c.1771C>T p.Q591* | Nonsense Mutation (SNP) | VAF 79/658 reads (12%) | called by muse, mutect2, varscan2
- F2 | c.1418C>T p.A473V | Missense Mutation (SNP) | VAF 115/765 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FAM124B | c.335C>T p.A112V | Missense Mutation (SNP) | VAF 60/896 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.085); called by muse, mutect2
- FAM20C | c.1079_1081del p.N360del | In Frame Del (DEL) | VAF 83/494 reads (17%) | called by pindel, varscan2
- FAM47A | c.379G>A p.A127T | Missense Mutation (SNP) | VAF 208/568 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- FAM83B | c.305C>A p.P102Q | Missense Mutation (SNP) | VAF 102/993 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAM83C | c.2059C>T p.H687Y | Missense Mutation (SNP) | VAF 126/1181 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- FANCB | c.82T>A p.S28T | Missense Mutation (SNP) | VAF 46/447 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.616); called by muse, mutect2, varscan2
- FASTK | c.55G>T p.A19S | Missense Mutation (SNP) | VAF 87/1856 reads (5%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); called by muse, mutect2
- FBF1 | c.2548_2568del p.Q850_A856del (on ENST00000586717; = p.Q864_A870del on NM_001319193.1) | In Frame Del (DEL) | VAF 121/708 reads (17%) | called by mutect2, pindel, varscan2
- FBRSL1 | c.2738C>T p.P913L | Missense Mutation (SNP) | VAF 64/1214 reads (5%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2
- FBXO15 | c.1193G>T p.R398I | Missense Mutation (SNP) | VAF 63/541 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- FBXO46 | c.1430C>T p.P477L | Missense Mutation (SNP) | VAF 110/883 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- FBXO46 | c.1328C>T p.T443I | Missense Mutation (SNP) | VAF 113/926 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.157); called by muse, varscan2
- FCRL1 | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 86/751 reads (11%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FGFR3 | c.861G>A p.W287* | Nonsense Mutation (SNP) | VAF 72/1081 reads (7%) | called by muse, mutect2
- FHAD1 | c.3536C>T p.S1179L | Missense Mutation (SNP) | VAF 132/544 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.031); called by muse, varscan2
- FHDC1 | c.2420C>T p.S807F | Missense Mutation (SNP) | VAF 131/844 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); called by muse, mutect2, varscan2
- FLNB | c.3870C>A p.Y1290* | Nonsense Mutation (SNP) | VAF 39/709 reads (6%) | called by muse, mutect2
- FMN2 | c.2053G>A p.D685N | Missense Mutation (SNP) | VAF 152/709 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- FRMD4B | c.2513C>T p.S838F | Missense Mutation (SNP) | VAF 302/916 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- FSCB | c.2123C>T p.P708L | Missense Mutation (SNP) | VAF 98/823 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- FSHR | c.1975T>G p.S659A | Missense Mutation (SNP) | VAF 100/607 reads (16%) | SIFT tolerated (0.51); PolyPhen benign (0.389); called by muse, mutect2, varscan2
- FURIN | c.1155T>C p.N385= | Splice Region (SNP) | VAF 126/547 reads (23%) | called by muse, mutect2, varscan2
- FYB2 | c.191C>T p.P64L | Missense Mutation (SNP) | VAF 89/614 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- FZD2 | c.1541T>A p.M514K | Missense Mutation (SNP) | VAF 124/989 reads (13%) | SIFT tolerated (0.5); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- GALR1 | c.922G>A p.E308K | Missense Mutation (SNP) | VAF 106/762 reads (14%) | SIFT tolerated (0.74); PolyPhen benign (0.406); called by muse, mutect2, varscan2
- GAS2L2 | c.852C>A p.F284L | Missense Mutation (SNP) | VAF 130/702 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GAS6 | c.1382C>G p.T461R | Missense Mutation (SNP) | VAF 50/821 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2
- GGT7 | c.1898C>T p.S633F | Missense Mutation (SNP) | VAF 106/1114 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- GIPC2 | c.409G>A p.G137S | Missense Mutation (SNP) | VAF 44/450 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GLRA3 | c.957G>A p.W319* | Nonsense Mutation (SNP) | VAF 54/397 reads (14%) | called by muse, mutect2, varscan2
- GLT6D1 | c.112C>T p.H38Y | Missense Mutation (SNP) | VAF 92/946 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.41); called by muse, mutect2
- GLTPD2 | c.625G>A p.D209N | Missense Mutation (SNP) | VAF 414/1256 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.386); called by muse, mutect2, varscan2
- GOLIM4 | c.886C>T p.P296S | Missense Mutation (SNP) | VAF 94/588 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- GPATCH8 | c.492G>A p.Q164= | Splice Region (SNP) | VAF 82/391 reads (21%) | called by muse, mutect2, varscan2
- GPSM2 | c.902C>T p.A301V | Missense Mutation (SNP) | VAF 67/505 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GPT2 | c.1310G>A p.G437E | Missense Mutation (SNP) | VAF 96/633 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GRM8 | c.2075C>T p.P692L | Missense Mutation (SNP) | VAF 137/916 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- GUCY2F | c.2789C>T p.T930I | Missense Mutation (SNP) | VAF 143/389 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GZMH | c.199G>A p.G67R | Missense Mutation (SNP) | VAF 58/398 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- H1-2 | c.497del p.V166Efs*28 | Frame Shift Del (DEL) | VAF 104/939 reads (11%) | called by mutect2, pindel, varscan2
- HACD2 | c.349C>A p.L117I | Missense Mutation (SNP) | VAF 229/720 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- HDLBP | c.241C>A p.H81N | Missense Mutation (SNP) | VAF 45/371 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.572); called by muse, mutect2, varscan2
- HEG1 | c.3497C>T p.S1166F | Missense Mutation (SNP) | VAF 62/504 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- HID1 | c.2304G>A p.R768= | Splice Region (SNP) | VAF 42/856 reads (5%) | called by muse, mutect2
- HIPK1 | c.3586G>A p.G1196R (on ENST00000369558 / NM_001369806.1; = p.G802R on NM_181358.2) | Missense Mutation (SNP) | VAF 90/645 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HIRA | c.1939C>T p.R647W | Missense Mutation (SNP) | VAF 237/820 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- HIVEP3 | c.5503G>A p.G1835R | Missense Mutation (SNP) | VAF 99/631 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HNRNPA0 | c.481C>T p.H161Y | Missense Mutation (SNP) | VAF 106/889 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HNRNPL | c.105G>A p.M35I | Missense Mutation (SNP) | VAF 186/1305 reads (14%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- HOXA9 | c.721C>T p.R241* | Nonsense Mutation (SNP) | VAF 78/1280 reads (6%) | called by muse, mutect2
- ICAM5 | c.2053G>A p.A685T | Missense Mutation (SNP) | VAF 128/1020 reads (13%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.478); called by muse, mutect2, varscan2
- IGFBP2 | c.706G>A p.E236K | Missense Mutation (SNP) | VAF 137/681 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); called by muse, mutect2, varscan2
- IGKV2D-26 | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 74/709 reads (10%) | SIFT tolerated (0.86); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- IL18 | c.361G>A p.E121K | Missense Mutation (SNP) | VAF 30/278 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.056); called by muse, mutect2
- IL1R2 | c.140C>T p.A47V | Missense Mutation (SNP) | VAF 227/907 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- IL1RAPL2 | c.41T>C p.V14A | Missense Mutation (SNP) | VAF 41/403 reads (10%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- IRAG1 | c.386C>T p.S129F | Missense Mutation (SNP) | VAF 78/756 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- ITGAL | c.790G>A p.D264N | Missense Mutation (SNP) | VAF 118/847 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ITGAL | c.3367G>A p.E1123K | Missense Mutation (SNP) | VAF 60/630 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2
- ITM2A | c.517C>T p.P173S | Missense Mutation (SNP) | VAF 127/374 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KAT2B | c.1979C>T p.S660F | Missense Mutation (SNP) | VAF 98/656 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- KCNIP3 | c.16G>A p.E6K | Missense Mutation (SNP) | VAF 56/672 reads (8%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.08); called by muse, mutect2
- KCNN1 | c.286C>T p.R96W | Missense Mutation (SNP) | VAF 106/958 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCNQ4 | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 103/705 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.664); called by muse, mutect2, varscan2
- KDM5B | c.3381_3383delinsTC p.L1128Rfs*5 | Frame Shift Del (DEL) | VAF 83/879 reads (9%) | called by pindel, varscan2*
- KIF18A | c.91C>T p.H31Y | Missense Mutation (SNP) | VAF 81/674 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KLC1 | c.740C>T p.S247L | Missense Mutation (SNP) | VAF 85/672 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- KLF15 | c.152C>T p.S51F | Missense Mutation (SNP) | VAF 83/1024 reads (8%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.994); called by muse, mutect2
- KLF17 | c.829T>A p.S277T | Missense Mutation (SNP) | VAF 90/661 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.236); called by muse, mutect2, varscan2
- KLHDC7A | c.971G>A p.G324E | Missense Mutation (SNP) | VAF 111/836 reads (13%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2, varscan2
- KLHL25 | c.1742T>C p.V581A | Missense Mutation (SNP) | VAF 129/667 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.772); called by muse, mutect2, varscan2
- KLHL4 | c.439T>A p.S147T | Missense Mutation (SNP) | VAF 79/331 reads (24%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- KMT2B | c.2159C>T p.S720F | Missense Mutation (SNP) | VAF 102/882 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- KRT1 | c.68G>A p.G23E | Missense Mutation (SNP) | VAF 285/990 reads (29%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- KRTAP16-1 | c.20C>T p.S7F | Missense Mutation (SNP) | VAF 40/879 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.007); called by muse, mutect2
- KRTAP20-3 | c.128G>A p.W43* | Nonsense Mutation (SNP) | VAF 28/636 reads (4%) | called by muse, mutect2
- KSR1 | c.605C>T p.S202L (on ENST00000644974 / NM_001367810.1; = p.S65L on NM_014238.2) | Missense Mutation (SNP) | VAF 184/1182 reads (16%) | SIFT tolerated (0.35); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- LARGE2 | c.1136C>T p.P379L | Missense Mutation (SNP) | VAF 164/831 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- LAT2 | c.553G>A p.E185K | Missense Mutation (SNP) | VAF 228/1000 reads (23%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- LDHAL6A | c.556C>A p.H186N | Missense Mutation (SNP) | VAF 122/649 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LFNG | c.586T>C p.F196L (on ENST00000222725 / NM_001040167.2; = p.F67L on NM_002304.2) | Missense Mutation (SNP) | VAF 237/896 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.344); called by muse, mutect2, varscan2
- LHX8 | c.635C>T p.A212V | Missense Mutation (SNP) | VAF 63/490 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.386); called by muse, mutect2, varscan2
- LINC00514 | c.1132G>A p.G378S | Missense Mutation (SNP) | VAF 72/692 reads (10%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- LOXHD1 | c.1447C>T p.L483F | Missense Mutation (SNP) | VAF 155/805 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- LPAR4 | c.578C>T p.S193F | Missense Mutation (SNP) | VAF 154/550 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, varscan2
- LPCAT3 | c.430C>G p.P144A | Missense Mutation (SNP) | VAF 50/642 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- LRG1 | c.542C>T p.P181L | Missense Mutation (SNP) | VAF 175/886 reads (20%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.843); called by mutect2, varscan2
- LRP2 | c.11410C>T p.Q3804* | Nonsense Mutation (SNP) | VAF 40/667 reads (6%) | called by muse, mutect2
- LRRC46 | c.164G>A p.G55E | Missense Mutation (SNP) | VAF 79/690 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.701); called by muse, mutect2, varscan2
- LRRC9 | c.1133del p.L378Yfs*2 | Frame Shift Del (DEL) | VAF 72/641 reads (11%) | called by mutect2, pindel, varscan2
- LUZP4 | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 66/217 reads (30%) | SIFT tolerated (0.65); PolyPhen benign (0.138); called by muse, varscan2
- MAB21L4 | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 76/1096 reads (7%) | SIFT tolerated (0.34); PolyPhen benign (0.321); called by muse, mutect2
- MAGEB1 | c.901C>T p.P301S | Missense Mutation (SNP) | VAF 257/614 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- MAGEC2 | c.781G>T p.G261W | Missense Mutation (SNP) | VAF 60/716 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- MALRD1 | c.3053C>T p.S1018L | Missense Mutation (SNP) | VAF 70/558 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); called by muse, mutect2, varscan2
- MAML1 | c.1829C>T p.P610L | Missense Mutation (SNP) | VAF 166/916 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- MAP10 | c.1643C>T p.S548F | Missense Mutation (SNP) | VAF 140/627 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MARCOL | c.398G>A p.G133E | Missense Mutation (SNP) | VAF 123/579 reads (21%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MAST3 | c.2423C>T p.P808L | Missense Mutation (SNP) | VAF 111/1098 reads (10%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MAST4 | c.2578C>T p.P860S (on ENST00000403625 / NM_001164664.2; = p.P671S on NM_015183.3) | Missense Mutation (SNP) | VAF 60/610 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MB21D2 | c.1292G>T p.R431L | Missense Mutation (SNP) | VAF 129/773 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.031); called by muse, varscan2
- MB21D2 | c.241C>T p.P81S | Missense Mutation (SNP) | VAF 67/489 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- MCF2L2 | c.1930G>A p.G644R | Missense Mutation (SNP) | VAF 74/378 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MED13 | c.6496T>G p.L2166V | Missense Mutation (SNP) | VAF 58/569 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- MED9 | c.359G>A p.S120N | Missense Mutation (SNP) | VAF 52/884 reads (6%) | SIFT tolerated (0.44); PolyPhen benign (0.003); called by muse, mutect2
- MEI1 | c.1934G>A p.G645E | Missense Mutation (SNP) | VAF 68/833 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- MEP1B | c.476G>A p.G159E | Missense Mutation (SNP) | VAF 208/946 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- METTL24 | c.825G>T p.W275C | Missense Mutation (SNP) | VAF 215/708 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MRGPRX3 | c.961G>A p.E321K | Missense Mutation (SNP) | VAF 79/507 reads (16%) | SIFT tolerated (0.87); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- MROH2B | c.2276T>A p.I759N | Missense Mutation (SNP) | VAF 63/451 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, varscan2
- MRPL19 | c.287G>A p.R96K | Missense Mutation (SNP) | VAF 48/423 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MTF2 | c.820C>T p.L274F | Missense Mutation (SNP) | VAF 46/354 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MTFR1 | c.189G>C p.W63C | Missense Mutation (SNP) | VAF 40/706 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.037); called by muse, mutect2
- MTNR1A | c.592G>T p.V198F | Missense Mutation (SNP) | VAF 107/662 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.233); called by muse, mutect2, varscan2
- MUC16 | c.6800C>T p.P2267L | Missense Mutation (SNP) | VAF 49/811 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.958); called by muse, mutect2
- MUC2 | c.4030C>T p.P1344S | Missense Mutation (SNP) | VAF 91/816 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- MUC22 | c.3416C>T p.S1139F | Missense Mutation (SNP) | VAF 118/1078 reads (11%) | SIFT deleterious (0); called by muse, varscan2
- MXRA5 | c.4630G>A p.V1544M | Missense Mutation (SNP) | VAF 66/373 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- MYEF2 | c.1769G>C p.R590T | Missense Mutation (SNP) | VAF 118/576 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- MYH7 | c.1337C>T p.T446I | Missense Mutation (SNP) | VAF 109/834 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.799); called by muse, mutect2, varscan2
- MYH7B | c.4624G>C p.A1542P | Missense Mutation (SNP) | VAF 112/1194 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.306); called by muse, mutect2
- MYH8 | c.4579C>T p.H1527Y | Missense Mutation (SNP) | VAF 46/782 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.127); called by muse, mutect2
- MYLK2 | c.980T>C p.V327A | Missense Mutation (SNP) | VAF 182/710 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.551); called by muse, mutect2, varscan2
- MYO15A | c.2297G>A p.R766Q | Missense Mutation (SNP) | VAF 334/1094 reads (31%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MYO18A | c.5396C>T p.A1799V | Missense Mutation (SNP) | VAF 105/624 reads (17%) | SIFT tolerated (0.75); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- MYO18B | c.2494C>T p.H832Y | Missense Mutation (SNP) | VAF 116/936 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MYO7A | c.5534C>T p.P1845L | Missense Mutation (SNP) | VAF 142/901 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MYRF | c.241G>A p.G81R (on ENST00000278836 / NM_001127392.3; = p.G72R on NM_013279.4) | Missense Mutation (SNP) | VAF 164/1050 reads (16%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- NAALADL2 | c.952G>A p.E318K | Missense Mutation (SNP) | VAF 42/793 reads (5%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.94); called by muse, mutect2
- NBPF1 | c.2344C>T p.L782F | Missense Mutation (SNP) | VAF 115/1615 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); called by muse, mutect2
- NCAPH2 | c.736T>C p.S246P | Missense Mutation (SNP) | VAF 64/970 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.425); called by muse, mutect2
- NCKAP1L | c.1099C>T p.L367F | Missense Mutation (SNP) | VAF 28/611 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2
- NCKIPSD | c.809C>T p.P270L | Missense Mutation (SNP) | VAF 54/1056 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.045); called by muse, mutect2
- NEK11 | c.1093G>A p.E365K | Missense Mutation (SNP) | VAF 36/469 reads (8%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.921); called by muse, mutect2
- NEMF | c.1577G>A p.W526* | Nonsense Mutation (SNP) | VAF 48/367 reads (13%) | called by muse, mutect2, varscan2
- NETO1 | c.1285C>T p.H429Y | Missense Mutation (SNP) | VAF 146/678 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- NFATC1 | c.506C>G p.S169W | Missense Mutation (SNP) | VAF 119/1030 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- NFKBIZ | c.7G>T p.V3L | Missense Mutation (SNP) | VAF 116/665 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- NLRP4 | c.2906T>A p.L969H | Missense Mutation (SNP) | VAF 38/648 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2
- NLRP6 | c.2248G>A p.E750K | Missense Mutation (SNP) | VAF 147/780 reads (19%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- NOC4L | c.1097C>T p.A366V | Missense Mutation (SNP) | VAF 86/782 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NPIPB11 | c.3206C>T p.P1069L | Missense Mutation (SNP) | VAF 28/853 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- NR3C2 | c.2111C>T p.P704L | Missense Mutation (SNP) | VAF 73/434 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- NRXN3 | c.697C>T p.L233F | Missense Mutation (SNP) | VAF 68/509 reads (13%) | SIFT tolerated (0.82); PolyPhen benign (0.003); called by muse, mutect2, varscan2
765 further variants in this file (184 protein-altering or splice-affecting, 520 silent, 61 other) are not listed here.
